Somatic mutation profile of tumor specimen TCGA-FI-A2D5-01A (aliquot TCGA-FI-A2D5-01A-11D-A17D-09) from TCGA case TCGA-FI-A2D5, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IVB; Tumor grade: G3; Age at diagnosis: 56.6 years (20,666 days).
Specimen TCGA-FI-A2D5-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 65ab25c8-fb41-41c0-99f5-cf3f6b615f70.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-FI-A2D5-10A (Blood Derived Normal), aliquot TCGA-FI-A2D5-10A-01D-A17D-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/fc97ede5-89d6-4778-90aa-ddc00530a54d

The open-access MAF lists 16,074 somatic variants for this specimen: 11,959 protein-altering or splice-affecting, 3,745 silent, 370 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 10,969, Silent 3,745, Nonsense Mutation 648, Intron 173, Splice Site 168, Splice Region 108, RNA 95, 3'Flank 29, 3'UTR 27, Frame Shift Ins 24, 5'UTR 24, Frame Shift Del 22.

Variants (750 of 16,074; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADGRG1 | c.113G>A p.R38Q | Missense Mutation (SNP) | VAF 12/63 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs764367185, CM053914, COSV65636439; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ALPL | c.215T>C p.I72T | Missense Mutation (SNP) | VAF 15/56 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs781264043, CM045931; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- APC | c.1690C>T p.R564* | Nonsense Mutation (SNP) | VAF 10/72 reads (14%) | hotspot (GDC flag); catalogued as rs137854574, CM920035, COSV57321509; ClinVar: pathogenic; called by mutect2, varscan2
- ARID1A | c.5965C>T p.R1989* | Nonsense Mutation (SNP) | VAF 27/63 reads (43%) | hotspot (GDC flag); catalogued as rs879255270, CM1311944, COSV61370535; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ASPM | c.4732C>T p.R1578* | Nonsense Mutation (SNP) | VAF 9/32 reads (28%) | catalogued as rs753406334, COSV54125634; ClinVar: pathogenic; called by muse, mutect2, varscan2
- BCL6 | c.1781G>A p.R594Q | Missense Mutation (SNP) | VAF 31/78 reads (40%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen benign (0.267); catalogued as COSV51649761; called by muse, mutect2, varscan2
- BMPR2 | c.247+1G>A p.X83_splice | Splice Site (SNP) | VAF 4/14 reads (29%) | catalogued as rs1085307188, CD086220, CS1513974, COSV104424178; ClinVar: pathogenic; called by muse, varscan2
- BRAF | c.1450C>T p.R484W (on ENST00000288602 / NM_001374244.1; = p.R444W on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 19/45 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.112); catalogued as rs121913371, COSV56083156; ClinVar: likely pathogenic; called by muse, mutect2
- CACNA1F | c.1309+1G>A p.X437_splice | Splice Site (SNP) | VAF 38/85 reads (45%) | catalogued as rs782575860, COSV59904308; ClinVar: pathogenic; called by muse, varscan2
- CASR | c.206G>A p.R69H | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); catalogued as rs193922432, CM125651, CM149032, COSV56134554; ClinVar: uncertain significance / likely pathogenic; called by mutect2, varscan2
- CFAP53 | c.121C>T p.R41* | Nonsense Mutation (SNP) | VAF 10/51 reads (20%) | catalogued as rs375801610, CM151920; ClinVar: pathogenic; called by muse, mutect2, varscan2
- COL6A2 | c.1096C>T p.R366* | Nonsense Mutation (SNP) | VAF 47/124 reads (38%) | catalogued as rs387906609, CM093073, COSV100153522; ClinVar: pathogenic; called by muse, mutect2, varscan2
- CTNNB1 | c.1004A>C p.K335T | Missense Mutation (SNP) | VAF 21/70 reads (30%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV62688046, COSV62689047, COSV62695316; called by muse, mutect2, varscan2
- DGKE | c.1009C>T p.R337* | Nonsense Mutation (SNP) | VAF 13/36 reads (36%) | catalogued as rs762576212; ClinVar: pathogenic; called by muse, mutect2, varscan2
- DICER1 | c.1174C>T p.R392* | Nonsense Mutation (SNP) | VAF 12/36 reads (33%) | catalogued as rs1131691211, COSV100601828; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- DMD | c.7657C>T p.R2553* | Nonsense Mutation (SNP) | VAF 34/97 reads (35%) | catalogued as rs398124050, CM040026, COSV58905803; ClinVar: pathogenic; called by muse, mutect2, varscan2
- DNAH11 | c.13069C>T p.R4357* | Nonsense Mutation (SNP) | VAF 8/34 reads (24%) | catalogued as rs775720394, COSV60978335; ClinVar: pathogenic; called by muse, varscan2
- DNAI2 | c.883C>T p.R295* | Nonsense Mutation (SNP) | VAF 9/59 reads (15%) | catalogued as rs200708870; ClinVar: pathogenic; called by mutect2, varscan2
- DPYD | c.1681C>T p.R561* | Nonsense Mutation (SNP) | VAF 8/27 reads (30%) | catalogued as rs1057516968, CM161357, COSV64613429; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- DSP | c.3316G>T p.E1106* | Nonsense Mutation (SNP) | VAF 4/17 reads (24%) | catalogued as rs1131691673, COSV65791931; ClinVar: likely pathogenic; called by muse, mutect2
- EDNRB | c.871C>T p.R291* (on ENST00000377211 / NM_001201397.1; = p.R201* on NM_000115.5) | Nonsense Mutation (SNP) | VAF 6/17 reads (35%) | catalogued as rs104894391, CM020406; ClinVar: pathogenic; called by muse, mutect2, varscan2
- FBXW7 | c.1322G>A p.R441Q (on ENST00000281708 / NM_001349798.2; = p.R361Q on NM_018315.5) | Missense Mutation (SNP) | VAF 29/101 reads (29%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen probably damaging (0.971); catalogued as COSV55898232, COSV55900020, COSV55902900; called by muse, mutect2, varscan2
- FKBP10 | c.337G>A p.E113K | Missense Mutation (SNP) | VAF 6/58 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as rs397514674, CM130011, COSV58637640; ClinVar: pathogenic; called by mutect2, varscan2
- GALC | c.908+1G>A p.X303_splice | Splice Site (SNP) | VAF 8/17 reads (47%) | catalogued as rs750524447, CS1110644, COSV99728750; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- GFM1 | c.700C>T p.R234* | Nonsense Mutation (SNP) | VAF 7/34 reads (21%) | catalogued as rs863224032; ClinVar: pathogenic; called by mutect2, varscan2
- GRHPR | c.905G>A p.R302H | Missense Mutation (SNP) | VAF 19/52 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs180177323, CM073113, CM1511298, COSV57039728; ClinVar: pathogenic; called by muse, mutect2, varscan2
- GRIN2B | c.1916C>T p.A639V | Missense Mutation (SNP) | VAF 10/73 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs797044930, CM162111, COSV74206357; ClinVar: pathogenic; called by muse, mutect2, varscan2
- HDAC8 | c.496C>T p.R166* | Nonsense Mutation (SNP) | VAF 18/54 reads (33%) | catalogued as rs886041936; ClinVar: pathogenic; called by muse, mutect2, varscan2
- HUWE1 | c.9208C>T p.R3070C | Missense Mutation (SNP) | VAF 6/53 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs886041876, COSV53358976; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- IL7R | c.616C>T p.R206* | Nonsense Mutation (SNP) | VAF 7/22 reads (32%) | hotspot (GDC flag); catalogued as rs201559094, CM045175, COSV57405649; called by muse, mutect2, varscan2
- IL7R | c.1185G>T p.K395N | Missense Mutation (SNP) | VAF 8/70 reads (11%) | hotspot (GDC flag); SIFT tolerated (0.4); PolyPhen benign (0.361); catalogued as COSV57407433; called by muse, varscan2
- KCNH2 | c.2509G>A p.D837N | Missense Mutation (SNP) | VAF 13/80 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs199473005, CM097520, CM097725; ClinVar: not provided / likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- KCNH2 | c.1468G>A p.A490T | Missense Mutation (SNP) | VAF 34/100 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as rs28928905, CM073156, CM097437; ClinVar: not provided / pathogenic; called by muse, varscan2
- KDM6A | c.2832+1G>A p.X944_splice | Splice Site (SNP) | VAF 14/43 reads (33%) | catalogued as rs1135401809, COSV65037460, COSV65040731; ClinVar: pathogenic; called by muse, mutect2, varscan2
- LAMA2 | c.149C>T p.A50V | Missense Mutation (SNP) | VAF 41/106 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs191899712; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- MSH6 | c.2836G>T p.E946* | Nonsense Mutation (SNP) | VAF 6/20 reads (30%) | catalogued as rs1558666905, COSV52274084; ClinVar: pathogenic; called by muse, varscan2
- MYH7 | c.4300C>T p.R1434C | Missense Mutation (SNP) | VAF 14/49 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs730880800, CM115853, COSV62517542; ClinVar: pathogenic / uncertain significance; called by muse, mutect2, varscan2
- MYH7 | c.3622G>A p.D1208N | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs730880781, CM1411010; ClinVar: uncertain significance / likely pathogenic; called by mutect2, varscan2
- MYO5B | c.1966C>T p.R656C | Missense Mutation (SNP) | VAF 24/60 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs121908105, CM085574, COSV53222784; ClinVar: pathogenic; called by muse, mutect2, varscan2
- NDUFS4 | c.316C>T p.R106* | Nonsense Mutation (SNP) | VAF 8/58 reads (14%) | catalogued as rs104893898, CM002072; ClinVar: pathogenic; called by mutect2, varscan2
- NEK1 | c.1618C>T p.R540* | Nonsense Mutation (SNP) | VAF 16/86 reads (19%) | catalogued as rs758677637, COSV101455906; ClinVar: pathogenic; called by muse, mutect2, varscan2
- NRXN1 | c.3719-1416C>T | Intron (SNP) | VAF 13/54 reads (24%) | catalogued as rs1201575289, COSV60500247; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- OTX2 | c.202C>T p.R68* (on ENST00000408990 / NM_172337.3; = p.R76* on NM_021728.4) | Nonsense Mutation (SNP) | VAF 13/44 reads (30%) | catalogued as rs773157352, COSV59766871; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PANK2 | c.1441C>T p.R481* (on ENST00000316562 / NM_153638.3; = p.R190* on NM_024960.6 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 31/87 reads (36%) | catalogued as rs137852968, CM023193, COSV57255385; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.263G>A p.R88Q | Missense Mutation (SNP) | VAF 18/49 reads (37%) | hotspot (GDC flag); SIFT tolerated (0.06); PolyPhen probably damaging (0.971); catalogued as rs121913287, CM126688, COSV55874568, COSV55924241; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.3012G>T p.M1004I | Missense Mutation (SNP) | VAF 15/41 reads (37%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen benign (0.047); catalogued as COSV55881019, COSV55891097; called by muse, mutect2, varscan2
- PKHD1 | c.983G>A p.R328Q | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs770494581, CM149111, COSV61864021; ClinVar: uncertain significance / likely pathogenic; called by muse, mutect2, varscan2
- POLE | c.1231G>C p.V411L | Missense Mutation (SNP) | VAF 22/73 reads (30%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57676103, COSV57677068, COSV57683938; called by muse, mutect2, varscan2
- PSMB9 | c.494G>A p.G165D | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT tolerated (0.23); PolyPhen benign (0.028); catalogued as rs369359789, CM1511934; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PTEN | c.127G>T p.E43* | Nonsense Mutation (SNP) | VAF 25/84 reads (30%) | catalogued as rs1554893808, CM110124, COSV64297332, COSV64308587, COSV64311451; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PTEN | c.517C>T p.R173C | Missense Mutation (SNP) | VAF 16/46 reads (35%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.966); catalogued as rs121913293, CM074467, COSV64288569, COSV64310838; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- RPGR | c.1120G>T p.E374* | Nonsense Mutation (SNP) | VAF 14/39 reads (36%) | catalogued as rs62635001, CM971314, COSV100139548; ClinVar: not provided / likely pathogenic; called by muse, mutect2, varscan2
- RPGRIP1L | c.1945C>T p.R649* | Nonsense Mutation (SNP) | VAF 6/46 reads (13%) | catalogued as rs751477523, CM1212113, COSV50905127; ClinVar: pathogenic; called by mutect2, varscan2
- RYR2 | c.365G>A p.R122H | Missense Mutation (SNP) | VAF 48/112 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.974); catalogued as rs727503396, COSV63664819; ClinVar: uncertain significance / likely pathogenic; called by muse, mutect2, varscan2
- RYR2 | c.506G>A p.R169Q | Missense Mutation (SNP) | VAF 15/33 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.833); catalogued as rs397516539, CM065450, CM156349, COSV63686290; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- RYR2 | c.13489C>T p.R4497C | Missense Mutation (SNP) | VAF 23/80 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs121918600, CM010137; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- SBF2 | c.1459C>T p.R487* | Nonsense Mutation (SNP) | VAF 13/82 reads (16%) | catalogued as rs120074139, CM042330; ClinVar: pathogenic / uncertain significance; called by muse, mutect2, varscan2
- SCAPER | c.1081C>T p.R361* | Nonsense Mutation (SNP) | VAF 6/14 reads (43%) | catalogued as rs777893794; ClinVar: likely pathogenic; called by mutect2, varscan2
- SH3TC2 | c.1A>G p.M1? | Translation Start Site (SNP) | VAF 11/46 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.058); catalogued as rs864309709, CM136111; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- SHANK3 | c.2054G>A p.R685H | Missense Mutation (SNP) | VAF 13/46 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.139); catalogued as rs1064796528; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- SLC25A13 | c.1813C>T p.R605* | Nonsense Mutation (SNP) | VAF 10/26 reads (38%) | catalogued as rs80338729, CM003063, COSV55711009; ClinVar: pathogenic; called by muse, varscan2
- SLC5A1 | c.83A>G p.D28G | Missense Mutation (SNP) | VAF 8/68 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); catalogued as rs121912669, CM961318; ClinVar: pathogenic; called by mutect2, varscan2
- SMARCA4 | c.3575G>A p.R1192H | Missense Mutation (SNP) | VAF 16/34 reads (47%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60785906, COSV60794673; called by muse, varscan2
- TBC1D4 | c.3122G>A p.R1041H | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs199560195; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TBCD | c.2314C>T p.R772C | Missense Mutation (SNP) | VAF 26/70 reads (37%) | SIFT deleterious (0.03); PolyPhen benign (0.28); catalogued as rs181969865, COSV62798029; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TMEM67 | c.514C>T p.R172* | Nonsense Mutation (SNP) | VAF 17/48 reads (35%) | catalogued as rs765468645, CM161270, COSV60036423, COSV60043047; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- TMEM70 | c.238C>T p.R80* | Nonsense Mutation (SNP) | VAF 31/88 reads (35%) | catalogued as rs387907070, CM111396, COSV100383980; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TRIP4 | c.760C>T p.R254* | Nonsense Mutation (SNP) | VAF 12/46 reads (26%) | catalogued as rs869312827, CM162647, COSV56030281; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TSC2 | c.886G>A p.V296M | Missense Mutation (SNP) | VAF 8/53 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs747237113; ClinVar: likely pathogenic / likely benign; called by mutect2, varscan2
- XPO1 | c.2246G>A p.R749Q | Missense Mutation (SNP) | VAF 21/50 reads (42%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.922); catalogued as COSV68944577, COSV68946813; called by muse, mutect2, varscan2
- ZNF462 | c.3202C>T p.R1068* | Nonsense Mutation (SNP) | VAF 5/32 reads (16%) | catalogued as rs562767308, COSV52942682; ClinVar: pathogenic; called by mutect2, varscan2
- A1BG | c.782G>A p.R261H | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.531); catalogued as rs1258915234, COSV54049815; called by muse, mutect2, varscan2
- A1BG | c.239A>C p.Q80P | Missense Mutation (SNP) | VAF 8/53 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.79); catalogued as rs1415405096; called by muse, varscan2
- A2ML1 | c.445G>A p.V149I | Missense Mutation (SNP) | VAF 40/116 reads (34%) | SIFT tolerated (0.53); PolyPhen benign (0.014); catalogued as rs750354233, COSV55289718; called by muse, varscan2
- A2ML1 | c.3739G>T p.A1247S | Missense Mutation (SNP) | VAF 14/56 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1427087860; called by muse, mutect2, varscan2
- AACS | c.1823G>A p.R608H | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.479); catalogued as rs746208598; called by mutect2, varscan2
- AAMDC | c.133-1G>A p.X45_splice | Splice Site (SNP) | VAF 16/103 reads (16%) | catalogued as rs758721614, COSV59016865; called by muse, mutect2, varscan2
- AASDH | c.362C>A p.S121Y | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT tolerated (0.55); PolyPhen possibly damaging (0.793); catalogued as rs770368258, COSV52706622; called by muse, mutect2, varscan2
- AASS | c.728T>C p.V243A | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs761724579; called by muse, mutect2, varscan2
- ABCA1 | c.1106G>A p.R369H | Missense Mutation (SNP) | VAF 13/44 reads (30%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.937); catalogued as rs370223805; called by muse, mutect2, varscan2
- ABCA10 | c.3502G>A p.E1168K | Missense Mutation (SNP) | VAF 19/58 reads (33%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.567); catalogued as rs150472849; called by muse, mutect2, varscan2
- ABCA13 | c.12801G>T p.E4267D | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs757737367; called by muse, varscan2
- ABCA13 | c.14359G>A p.A4787T | Missense Mutation (SNP) | VAF 21/65 reads (32%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as rs200037299; called by muse, mutect2, varscan2
- ABCA3 | c.5098G>A p.A1700T | Missense Mutation (SNP) | VAF 23/58 reads (40%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as rs745625493, COSV57051086; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ABCA4 | c.2126C>T p.S709L | Missense Mutation (SNP) | VAF 14/46 reads (30%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs374152623; ClinVar: uncertain significance; called by muse, varscan2
- ABCA4 | c.1094G>T p.R365I | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT tolerated (0.08); PolyPhen benign (0.011); catalogued as rs768881855; called by muse, mutect2, varscan2
- ABCA5 | c.2399G>A p.S800N | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT tolerated (0.47); PolyPhen possibly damaging (0.51); catalogued as rs369145518; called by muse, varscan2
- ABCA7 | c.2309G>A p.R770Q | Missense Mutation (SNP) | VAF 17/43 reads (40%) | SIFT tolerated (0.73); PolyPhen benign (0.06); catalogued as rs768050490, COSV54026641; called by muse, varscan2
- ABCA7 | c.4301G>A p.R1434H | Missense Mutation (SNP) | VAF 8/47 reads (17%) | SIFT tolerated (0.24); PolyPhen benign (0.009); catalogued as rs369849959; called by mutect2, varscan2
- ABCB1 | c.3308G>A p.R1103Q | Missense Mutation (SNP) | VAF 16/41 reads (39%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as rs1266372866; called by muse, mutect2, varscan2
- ABCB11 | c.3329C>T p.A1110V | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs373956718, CM081500, COSV55589089; called by muse, mutect2, varscan2
- ABCB4 | c.3431G>A p.R1144Q (on ENST00000265723 / NM_018849.3; = p.R1137Q on NM_000443.4) | Missense Mutation (SNP) | VAF 15/100 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.595); catalogued as rs780738927, COSV55943540; called by muse, mutect2, varscan2
- ABCB4 | c.1774T>C p.S592P | Missense Mutation (SNP) | VAF 14/43 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs1280221721; called by muse, mutect2, varscan2
- ABCB5 | c.881T>C p.V294A | Missense Mutation (SNP) | VAF 10/64 reads (16%) | SIFT tolerated (0.62); PolyPhen benign (0.042); catalogued as COSV51718716; called by muse, mutect2, varscan2
- ABCB5 | c.2806G>A p.G936R (on ENST00000404938 / NM_001163941.2; = p.G491R on NM_178559.6) | Missense Mutation (SNP) | VAF 14/56 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.715); catalogued as rs776801339; called by muse, varscan2
- ABCB5 | c.2842C>T p.R948* (on ENST00000404938 / NM_001163941.2; = p.R503* on NM_178559.6) | Nonsense Mutation (SNP) | VAF 15/43 reads (35%) | catalogued as rs1158560751, COSV51705757; called by muse, varscan2
- ABCB6 | c.1226T>C p.F409S | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV54700290; called by muse, mutect2, varscan2
- ABCB6 | c.989G>A p.R330H | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs1436080788, COSV54693869, COSV54694307; called by muse, mutect2, varscan2
- ABCB7 | c.559A>G p.T187A (on ENST00000373394 / NM_001271696.3; = p.T188A on NM_004299.6) | Missense Mutation (SNP) | VAF 12/54 reads (22%) | SIFT tolerated (0.25); PolyPhen benign (0.101); catalogued as rs747643499; called by muse, mutect2, varscan2
- ABCB8 | c.1615C>T p.R539C (on ENST00000297504 / NM_001282291.2; = p.R522C on NM_007188.5) | Missense Mutation (SNP) | VAF 17/102 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.302); catalogued as rs767522915, COSV99873809; called by muse, mutect2, varscan2
- ABCC10 | c.206G>A p.R69Q (on ENST00000372530 / NM_001198934.2; = p.R26Q on NM_033450.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs750724181, COSV99766374, COSV99766572; called by mutect2, varscan2
- ABCC11 | c.3497G>A p.R1166H | Missense Mutation (SNP) | VAF 12/82 reads (15%) | SIFT tolerated (0.84); PolyPhen benign (0); catalogued as rs374295166; called by mutect2, varscan2
- ABCC12 | c.2231A>G p.K744R | Missense Mutation (SNP) | VAF 16/49 reads (33%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as rs1205513614; called by muse, mutect2, varscan2
- ABCC12 | c.1060T>C p.S354P | Missense Mutation (SNP) | VAF 24/91 reads (26%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV60912711; called by muse, mutect2, varscan2
- ABCC2 | c.2731C>T p.R911* | Nonsense Mutation (SNP) | VAF 29/56 reads (52%) | catalogued as rs756825916, COSV64985495; called by muse, mutect2, varscan2
- ABCC2 | c.4397C>T p.A1466V | Missense Mutation (SNP) | VAF 28/61 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as rs143844308; called by muse, mutect2, varscan2
- ABCC6 | c.4037C>A p.P1346H | Missense Mutation (SNP) | VAF 8/65 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52744328; called by muse, mutect2, varscan2
- ABCC8 | c.4097C>T p.A1366V | Missense Mutation (SNP) | VAF 24/83 reads (29%) | SIFT tolerated (0.46); PolyPhen benign (0.018); catalogued as rs746811190, CM1111099; called by muse, mutect2, varscan2
- ABCC8 | c.3578A>G p.D1193G | Missense Mutation (SNP) | VAF 36/91 reads (40%) | SIFT deleterious (0.02); PolyPhen benign (0.238); catalogued as CM078066; called by muse, mutect2, varscan2
- ABCC8 | c.2263C>T p.R755W | Missense Mutation (SNP) | VAF 14/60 reads (23%) | SIFT tolerated (0.08); PolyPhen benign (0.007); catalogued as rs748413285, COSV56854451; called by muse, varscan2
- ABCC8 | c.2182G>A p.G728R | Missense Mutation (SNP) | VAF 17/53 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56853650; called by muse, mutect2, varscan2
- ABCD2 | c.275G>A p.R92Q | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.162); catalogued as rs1023375791; called by muse, mutect2, varscan2
- ABCE1 | c.634C>T p.R212* | Nonsense Mutation (SNP) | VAF 21/63 reads (33%) | catalogued as COSV99668520; called by muse, mutect2, varscan2
- ABCF1 | c.349G>A p.A117T | Missense Mutation (SNP) | VAF 22/71 reads (31%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.06); catalogued as rs777204865; called by muse, mutect2, varscan2
- ABCF1 | c.2399G>A p.R800Q (on ENST00000326195 / NM_001025091.2; = p.R762Q on NM_001090.3) | Missense Mutation (SNP) | VAF 49/125 reads (39%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.701); catalogued as rs769559771, COSV58229863, COSV58230366; called by muse, mutect2, varscan2
- ABCG2 | c.19G>A p.E7K | Missense Mutation (SNP) | VAF 3/14 reads (21%) | SIFT tolerated (0.39); PolyPhen benign (0.001); catalogued as rs1272411168, COSV52948003; called by muse, mutect2
- ABHD16A | c.1463G>A p.R488Q | Missense Mutation (SNP) | VAF 27/60 reads (45%) | SIFT tolerated (0.47); PolyPhen benign (0.033); catalogued as rs756957697; called by muse, mutect2, varscan2
- ABHD17B | c.646A>G p.N216D | Missense Mutation (SNP) | VAF 12/47 reads (26%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.593); catalogued as COSV61007340; called by muse, mutect2, varscan2
- ABHD17B | c.479G>A p.R160H | Missense Mutation (SNP) | VAF 13/34 reads (38%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.803); catalogued as rs1194192922, COSV61007053; called by muse, varscan2
- ABHD17C | c.838G>A p.D280N | Missense Mutation (SNP) | VAF 26/74 reads (35%) | SIFT tolerated (0.06); PolyPhen benign (0.344); catalogued as rs766884861, COSV51916877; called by muse, mutect2, varscan2
- ABHD5 | c.193A>G p.T65A | Missense Mutation (SNP) | VAF 17/57 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs758048276; called by muse, mutect2, varscan2
- ABI3 | c.987C>A p.F329L | Missense Mutation (SNP) | VAF 13/49 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99865719; called by muse, varscan2
- ABLIM1 | c.1796G>A p.R599H | Missense Mutation (SNP) | VAF 24/68 reads (35%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.869); catalogued as rs754281771, COSV53306078; called by muse, mutect2, varscan2
- ABRA | c.863G>A p.R288H | Missense Mutation (SNP) | VAF 32/103 reads (31%) | SIFT tolerated (0.15); PolyPhen benign (0.156); catalogued as rs777760983; called by muse, mutect2, varscan2
- AC011448.1 | c.164G>A p.R55H | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.151); catalogued as rs759429885; called by muse, mutect2, varscan2
- AC013489.1 | c.455G>A p.R152H | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.483); catalogued as rs768947563; called by muse, mutect2, varscan2
- AC126283.2 | c.1291G>A p.A431T | Missense Mutation (SNP) | VAF 28/103 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs758017357, CM099903, COSV101144430; called by muse, mutect2, varscan2
- AC134980.2 | c.544C>T p.R182* | Nonsense Mutation (SNP) | VAF 12/86 reads (14%) | catalogued as rs202083008, COSV60907556; called by mutect2, varscan2
- ACAA1 | c.173A>G p.D58G | Missense Mutation (SNP) | VAF 10/84 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.315); catalogued as rs1198746850; called by muse, varscan2
- ACACA | c.2171G>A p.R724Q | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.714); catalogued as rs1017086449; called by mutect2, varscan2
- ACADS | c.826G>A p.A276T | Missense Mutation (SNP) | VAF 10/19 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs199717731, CM085210, COSV54367929; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ACAN | c.7100G>A p.G2367D (on ENST00000560601 / NM_001369268.1; = p.G2291D on NM_001135.3) | Missense Mutation (SNP) | VAF 23/62 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as rs780006455, COSV61368468; called by muse, mutect2, varscan2
- ACAN | c.7612C>T p.Q2538* (on ENST00000560601 / NM_001369268.1; = p.Q2500* on NM_013227.3) | Nonsense Mutation (SNP) | VAF 23/68 reads (34%) | catalogued as rs367553476; called by muse, mutect2, varscan2
- ACCSL | c.400G>A p.D134N | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT tolerated (0.34); PolyPhen benign (0.122); catalogued as rs748718263, COSV101122181; called by mutect2, varscan2
- ACKR1 | c.913G>A p.A305T | Missense Mutation (SNP) | VAF 12/83 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.089); catalogued as rs1216886104, COSV63674830; called by muse, mutect2, varscan2
- ACO2 | c.421C>T p.R141C | Missense Mutation (SNP) | VAF 16/51 reads (31%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.09); catalogued as rs745801074, COSV53442810; called by muse, mutect2, varscan2
- ACO2 | c.1690C>T p.R564C | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs781117483; called by mutect2, varscan2
- ACOT12 | c.620C>T p.A207V | Missense Mutation (SNP) | VAF 25/65 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1312509130, COSV56897719; called by muse, mutect2, varscan2
- ACOT7 | c.548G>A p.R183Q (on ENST00000377855 / NM_181864.3; = p.R173Q on NM_007274.4) | Missense Mutation (SNP) | VAF 8/64 reads (13%) | SIFT tolerated (0.33); PolyPhen benign (0.033); catalogued as rs1205245789; called by muse, mutect2, varscan2
- ACP3 | c.995G>A p.R332Q | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs370584472, COSV100313622; called by muse, mutect2
- ACSBG1 | c.1355C>T p.A452V | Missense Mutation (SNP) | VAF 17/54 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as rs763637644, COSV51910108; called by muse, mutect2, varscan2
- ACSF2 | c.953G>A p.G318D | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs755437990, COSV51974679; called by muse, varscan2
- ACSL3 | c.2159A>C p.K720T | Missense Mutation (SNP) | VAF 6/11 reads (55%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV62484314; called by muse, mutect2, varscan2
- ACSM2A | c.1019C>A p.S340Y (on ENST00000219054; = p.S261Y on NM_001308169.2) | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.288); catalogued as rs765780796, COSV99525415; called by mutect2, varscan2
- ACSM2B | c.1679G>A p.R560Q | Missense Mutation (SNP) | VAF 46/116 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs369392849; called by muse, varscan2
- ACSM3 | c.833C>T p.T278M | Missense Mutation (SNP) | VAF 9/65 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs755942547, COSV55499745; called by mutect2, varscan2
- ACSS3 | c.1694G>T p.R565I | Missense Mutation (SNP) | VAF 38/96 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54087208, COSV99699382; called by muse, mutect2
- ACTA1 | c.1096G>A p.E366K | Missense Mutation (SNP) | VAF 32/80 reads (40%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.973); catalogued as COSV64203738; called by muse, mutect2, varscan2
- ACTL6A | c.211G>T p.D71Y | Missense Mutation (SNP) | VAF 13/71 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as rs751915095, COSV66998812; called by muse, mutect2, varscan2
- ACTL7B | c.832C>T p.R278C | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.839); catalogued as rs1306606675, COSV65928227; called by muse, mutect2, varscan2
- ACTL8 | c.587G>A p.R196H | Missense Mutation (SNP) | VAF 14/47 reads (30%) | SIFT tolerated (0.44); PolyPhen benign (0); catalogued as rs770308852; called by muse, mutect2, varscan2
- ACTL9 | c.506C>T p.S169L | Missense Mutation (SNP) | VAF 16/80 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.863); catalogued as rs782701659, COSV61005127, COSV61007233; called by muse, mutect2, varscan2
- ACTN1 | c.244C>T p.R82* | Nonsense Mutation (SNP) | VAF 20/125 reads (16%) | catalogued as rs149484448; called by muse, mutect2, varscan2
- ACTN4 | c.194G>A p.R65Q | Missense Mutation (SNP) | VAF 19/87 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.901); catalogued as rs1307627747; called by muse, mutect2, varscan2
- ACTR2 | c.749G>A p.R250H | Missense Mutation (SNP) | VAF 16/95 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.096); catalogued as rs1420649037; called by muse, mutect2, varscan2
- ACTR3B | c.1226G>A p.R409H | Missense Mutation (SNP) | VAF 8/81 reads (10%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs1386959418, COSV55445946; called by muse, mutect2
- ACTRT1 | c.855G>T p.K285N | Missense Mutation (SNP) | VAF 11/65 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.137); catalogued as COSV100947610; called by muse, mutect2, varscan2
- ACVR1B | c.715C>T p.R239C | Missense Mutation (SNP) | VAF 10/54 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs760835152, COSV57777906, COSV99231572; called by mutect2, varscan2
- ADAD2 | c.844G>A p.D282N (on ENST00000315906 / NM_001145400.2; = p.D364N on NM_139174.4) | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs756983411; called by muse, mutect2, varscan2
- ADAM12 | c.1499C>T p.P500L | Missense Mutation (SNP) | VAF 8/58 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV64102651; called by muse, mutect2, varscan2
- ADAM17 | c.1931G>A p.R644Q | Missense Mutation (SNP) | VAF 37/99 reads (37%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs777431052; called by muse, mutect2, varscan2
- ADAM2 | c.2020C>T p.R674C | Missense Mutation (SNP) | VAF 14/33 reads (42%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.613); catalogued as rs200391854, COSV55864569; called by muse, mutect2, varscan2
- ADAMDEC1 | c.402G>T p.K134N | Missense Mutation (SNP) | VAF 9/20 reads (45%) | SIFT tolerated (0.11); PolyPhen benign (0.007); catalogued as rs1401817128, COSV56474251; called by muse, mutect2, varscan2
- ADAMDEC1 | c.554A>G p.H185R | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as rs1359549029; called by muse, mutect2, varscan2
- ADAMTS10 | c.3258C>A p.F1086L | Missense Mutation (SNP) | VAF 12/47 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.805); catalogued as COSV99546607; called by muse, mutect2, varscan2
- ADAMTS10 | c.556C>T p.R186C | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.96); catalogued as rs527419015; called by muse, mutect2
- ADAMTS12 | c.2012G>A p.G671D | Missense Mutation (SNP) | VAF 14/30 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV61277989; called by muse, mutect2, varscan2
- ADAMTS13 | c.2843C>T p.A948V | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT tolerated (0.46); PolyPhen benign (0.086); catalogued as rs781805469; called by muse, mutect2, varscan2
- ADAMTS14 | c.260G>A p.R87H | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.031); catalogued as rs61754837, COSV64600110; called by muse, mutect2, varscan2
- ADAMTS16 | c.1135C>T p.R379C | Missense Mutation (SNP) | VAF 15/47 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs200227089; called by muse, mutect2, varscan2
- ADAMTS16 | c.2636C>T p.S879F | Missense Mutation (SNP) | VAF 12/46 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56986370; called by muse, varscan2
- ADAMTS18 | c.3280C>T p.R1094* | Nonsense Mutation (SNP) | VAF 17/40 reads (43%) | catalogued as rs775431905, COSV51417329; called by muse, mutect2, varscan2
- ADAMTS18 | c.2600C>T p.T867I | Missense Mutation (SNP) | VAF 12/71 reads (17%) | SIFT tolerated (0.16); PolyPhen benign (0.163); catalogued as rs1404991315; called by muse, mutect2, varscan2
- ADAMTS2 | c.2014C>T p.R672C | Missense Mutation (SNP) | VAF 10/77 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as rs1253830096; called by muse, mutect2, varscan2
- ADAMTS3 | c.1235G>A p.G412D | Missense Mutation (SNP) | VAF 27/69 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54395420; called by muse, mutect2, varscan2
- ADAMTS3 | c.256G>A p.A86T | Missense Mutation (SNP) | VAF 16/63 reads (25%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.627); catalogued as COSV54402511; called by muse, mutect2, varscan2
- ADAMTS5 | c.2277A>C p.K759N | Missense Mutation (SNP) | VAF 11/30 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV53175355, COSV53186395; called by muse, mutect2, varscan2
- ADAMTS5 | c.1430G>A p.R477Q | Missense Mutation (SNP) | VAF 20/70 reads (29%) | SIFT tolerated (0.89); PolyPhen benign (0.007); catalogued as rs142161826, COSV99537274; called by muse, varscan2
- ADAMTSL1 | c.853G>A p.A285T | Missense Mutation (SNP) | VAF 26/76 reads (34%) | SIFT tolerated (0.3); PolyPhen benign (0.003); catalogued as rs748431522, COSV99444412; called by muse, mutect2, varscan2
- ADAMTSL1 | c.3064G>A p.D1022N | Missense Mutation (SNP) | VAF 16/27 reads (59%) | SIFT tolerated (0.28); PolyPhen probably damaging (0.918); catalogued as COSV65895881; called by muse, mutect2, varscan2
- ADAMTSL2 | c.2050G>A p.A684T | Missense Mutation (SNP) | VAF 12/49 reads (24%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.635); catalogued as rs1318297936; called by muse, mutect2, varscan2
- ADAMTSL4 | c.1454G>A p.R485H | Missense Mutation (SNP) | VAF 10/66 reads (15%) | SIFT tolerated (0.11); PolyPhen benign (0.012); catalogued as rs775230680; called by mutect2, varscan2
- ADAMTSL4 | c.2108G>A p.R703H | Missense Mutation (SNP) | VAF 13/49 reads (27%) | SIFT tolerated (0.55); PolyPhen benign (0.003); catalogued as rs201275872; called by muse, mutect2, varscan2
- ADAMTSL4 | c.2471C>T p.A824V | Missense Mutation (SNP) | VAF 11/59 reads (19%) | SIFT tolerated (0.44); PolyPhen benign (0.269); catalogued as rs377554910; called by muse, mutect2, varscan2
- ADARB1 | c.1991C>T p.A664V (on ENST00000360697 / NM_001346687.2; = p.A624V on NM_001112.4) | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT tolerated (0.2); PolyPhen benign (0.027); catalogued as rs138974538; called by mutect2, varscan2
- ADARB2 | c.1394T>C p.F465S | Missense Mutation (SNP) | VAF 14/54 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101186781; called by muse, mutect2, varscan2
- ADAT2 | c.297_298del p.L100Vfs*29 | Frame Shift Del (DEL) | VAF 20/62 reads (32%) | catalogued as rs763632407; called by pindel, varscan2
- ADCK2 | c.1001T>C p.V334A | Missense Mutation (SNP) | VAF 32/105 reads (30%) | SIFT tolerated (0.56); PolyPhen benign (0.003); catalogued as rs1563205704; called by muse, mutect2, varscan2
- ADCY10 | c.4454C>T p.A1485V | Missense Mutation (SNP) | VAF 29/113 reads (26%) | SIFT tolerated (0.37); PolyPhen benign (0.05); catalogued as COSV100896742; called by muse, mutect2, varscan2
- ADCY10 | c.2053G>A p.A685T | Missense Mutation (SNP) | VAF 11/80 reads (14%) | SIFT tolerated (0.63); PolyPhen benign (0.011); catalogued as rs887566449; called by muse, mutect2, varscan2
- ADCY2 | c.2255C>A p.S752Y | Missense Mutation (SNP) | VAF 27/79 reads (34%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.976); catalogued as COSV57886343; called by muse, varscan2
- ADCY3 | c.2350G>A p.A784T | Missense Mutation (SNP) | VAF 19/50 reads (38%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs749337506; called by muse, mutect2, varscan2
- ADCY5 | c.2872G>A p.A958T | Missense Mutation (SNP) | VAF 13/45 reads (29%) | SIFT tolerated (0.35); PolyPhen benign (0.047); catalogued as rs764072307, COSV100567452; called by muse, mutect2, varscan2
- ADCY5 | c.1094C>T p.A365V | Missense Mutation (SNP) | VAF 10/58 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0.045); catalogued as rs769526316; called by muse, mutect2, varscan2
- ADCY5 | c.868C>T p.R290C | Missense Mutation (SNP) | VAF 22/70 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.899); catalogued as rs749651565; called by muse, varscan2
- ADCY6 | c.2008G>A p.G670R | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.286); catalogued as rs55726827; called by muse, mutect2, varscan2
- ADCY6 | c.65G>A p.R22H | Missense Mutation (SNP) | VAF 14/47 reads (30%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.038); catalogued as rs758846729; called by muse, mutect2, varscan2
- ADCY7 | c.439G>A p.A147T | Missense Mutation (SNP) | VAF 14/63 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs200651932, COSV54272373; called by muse, mutect2, varscan2
- ADCY7 | c.1549C>T p.R517W | Missense Mutation (SNP) | VAF 22/46 reads (48%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.849); catalogued as rs373164090; called by muse, mutect2, varscan2
- ADCY9 | c.3580G>A p.A1194T | Missense Mutation (SNP) | VAF 23/56 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs769546776; called by muse, mutect2, varscan2
- ADCYAP1R1 | c.554G>A p.R185H | Missense Mutation (SNP) | VAF 26/74 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs745856523, COSV58443114; called by muse, varscan2
- ADD1 | c.1727G>A p.R576H | Missense Mutation (SNP) | VAF 20/48 reads (42%) | SIFT tolerated (0.08); PolyPhen benign (0.02); catalogued as rs775344885; called by muse, mutect2, varscan2
- ADD2 | c.1433G>A p.R478H | Missense Mutation (SNP) | VAF 20/87 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.943); catalogued as rs150426440; called by muse, mutect2, varscan2
- ADD2 | c.400C>T p.R134W | Missense Mutation (SNP) | VAF 21/46 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52455754; called by muse, mutect2, varscan2
- ADGRB2 | c.2982C>T p.G994= | Splice Region (SNP) | VAF 11/37 reads (30%) | catalogued as rs775422771; called by muse, mutect2, varscan2
- ADGRG4 | c.2099C>T p.T700I | Missense Mutation (SNP) | VAF 18/49 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.5); catalogued as COSV54967521; called by muse, mutect2, varscan2
- ADGRG4 | c.3256C>T p.R1086C | Missense Mutation (SNP) | VAF 32/73 reads (44%) | SIFT deleterious (0.03); PolyPhen benign (0.005); catalogued as rs866052593, COSV54949311; called by muse, mutect2, varscan2
- ADGRG4 | c.3467C>T p.A1156V | Missense Mutation (SNP) | VAF 29/85 reads (34%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs748422787; called by muse, varscan2
- ADGRG4 | c.8599A>G p.I2867V | Missense Mutation (SNP) | VAF 11/69 reads (16%) | SIFT tolerated (0.14); PolyPhen benign (0.1); catalogued as rs1186310914; called by muse, mutect2, varscan2
- ADGRG6 | c.1003G>A p.D335N | Missense Mutation (SNP) | VAF 20/52 reads (38%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.753); catalogued as rs373599767; called by muse, mutect2, varscan2
- ADGRL1 | c.902G>A p.R301H (on ENST00000340736 / NM_001008701.3; = p.R296H on NM_014921.5) | Missense Mutation (SNP) | VAF 15/65 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs201495192, COSV100529155; called by muse, mutect2, varscan2
- ADGRL2 | c.2767G>A p.A923T (on ENST00000370717 / NM_001366005.1; = p.A910T on NM_012302.4) | Missense Mutation (SNP) | VAF 4/37 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.672); catalogued as COSV99590011; called by muse, varscan2
- ADGRL2 | c.2771C>A p.A924D (on ENST00000370717 / NM_001366005.1; = p.A911D on NM_012302.4) | Missense Mutation (SNP) | VAF 13/35 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.349); catalogued as COSV54669370; called by muse, varscan2
- ADGRL3 | c.3595C>T p.R1199* (on ENST00000506720 / NM_001322402.2; = p.R1131* on NM_015236.6) | Nonsense Mutation (SNP) | VAF 7/41 reads (17%) | catalogued as COSV72230748, COSV72232434; called by muse, mutect2, varscan2
- ADIPOQ | c.406T>G p.F136V | Missense Mutation (SNP) | VAF 11/55 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.915); catalogued as rs764136071; called by mutect2, varscan2
- ADIPOR2 | c.916G>A p.A306T | Missense Mutation (SNP) | VAF 16/44 reads (36%) | SIFT tolerated (0.58); PolyPhen benign (0.01); catalogued as rs750803822, COSV63945473; called by muse, mutect2, varscan2
- ADNP2 | c.2114C>T p.S705F | Missense Mutation (SNP) | VAF 18/51 reads (35%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as rs780038294; called by muse, mutect2, varscan2
- ADORA1 | c.98C>T p.A33V | Missense Mutation (SNP) | VAF 18/103 reads (17%) | SIFT tolerated (0.45); PolyPhen possibly damaging (0.808); catalogued as COSV58810079; called by muse, varscan2
- ADORA1 | c.374C>T p.A125V | Missense Mutation (SNP) | VAF 12/75 reads (16%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as rs79599913; called by mutect2, varscan2
- ADRA2B | c.617G>A p.G206D | Missense Mutation (SNP) | VAF 12/26 reads (46%) | SIFT tolerated (0.61); PolyPhen benign (0.215); catalogued as rs746574455; called by muse, varscan2
- ADRA2B | c.262T>C p.Y88H | Missense Mutation (SNP) | VAF 11/58 reads (19%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.897); catalogued as rs764744451; called by muse, mutect2, varscan2
- ADRA2C | c.275C>T p.S92L | Missense Mutation (SNP) | VAF 22/97 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1260543085; called by muse, varscan2
- ADRB3 | c.659T>C p.M220T | Missense Mutation (SNP) | VAF 13/27 reads (48%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs1255543740; called by muse, mutect2, varscan2
- ADSS2 | c.1076C>T p.A359V | Missense Mutation (SNP) | VAF 20/46 reads (43%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.978); catalogued as rs1337381260, COSV100836816; called by muse, varscan2
- AFAP1 | c.2003C>T p.S668F | Missense Mutation (SNP) | VAF 16/68 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as COSV100631480, COSV61795722; called by muse, mutect2, varscan2
- AFAP1L2 | c.668G>T p.S223I | Missense Mutation (SNP) | VAF 13/85 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.345); catalogued as COSV100412124; called by muse, mutect2, varscan2
- AFDN | c.532C>T p.R178* | Nonsense Mutation (SNP) | VAF 24/60 reads (40%) | catalogued as COSV60041076; called by muse, mutect2, varscan2
- AFDN | c.2585A>G p.D862G | Missense Mutation (SNP) | VAF 10/66 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs111563192; called by mutect2, varscan2
- AFDN | c.4906C>T p.R1636W (on ENST00000447894 / NM_001366320.1; = p.R1634W on NM_001040000.3) | Missense Mutation (SNP) | VAF 28/66 reads (42%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0); catalogued as rs368769724, COSV100653912; called by muse, mutect2, varscan2
- AFF3 | c.2843C>T p.P948L | Missense Mutation (SNP) | VAF 29/79 reads (37%) | SIFT tolerated (0.37); PolyPhen benign (0.005); catalogued as rs1347906445, COSV100418230; called by muse, mutect2, varscan2
- AFG1L | c.1063C>T p.P355S | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as rs765868026; called by muse, varscan2
- AFM | c.113T>G p.F38C | Missense Mutation (SNP) | VAF 23/65 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.966); catalogued as COSV56919646; called by muse, mutect2, varscan2
- AFM | c.466G>T p.E156* | Nonsense Mutation (SNP) | VAF 10/28 reads (36%) | catalogued as COSV56919653; called by muse, mutect2, varscan2
- AFM | c.523G>A p.A175T | Missense Mutation (SNP) | VAF 6/35 reads (17%) | SIFT tolerated (0.05); PolyPhen benign (0.072); catalogued as rs771719904, COSV56919283, COSV56920023; called by mutect2, varscan2
- AFMID | c.748G>A p.E250K | Missense Mutation (SNP) | VAF 16/71 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs374429075; called by muse, mutect2, varscan2
- AGAP1 | c.2428C>T p.R810W (on ENST00000304032 / NM_001037131.3; = p.R757W on NM_014914.5) | Missense Mutation (SNP) | VAF 17/128 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.955); catalogued as rs781432875; called by muse, mutect2, varscan2
- AGAP2 | c.2564G>A p.R855H | Missense Mutation (SNP) | VAF 8/64 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs375555113; called by mutect2, varscan2
- AGBL1 | c.1559G>T p.R520I | Missense Mutation (SNP) | VAF 22/55 reads (40%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.851); catalogued as COSV66856573; called by muse, mutect2, varscan2
- AGBL5 | c.10C>T p.R4C | Missense Mutation (SNP) | VAF 28/85 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs751461917, COSV59936080; called by muse, mutect2, varscan2
- AGBL5 | c.116C>T p.A39V | Missense Mutation (SNP) | VAF 11/81 reads (14%) | SIFT tolerated (0.21); PolyPhen benign (0.035); catalogued as COSV104403741; called by muse, mutect2, varscan2
- AGBL5 | c.1498C>T p.R500C | Missense Mutation (SNP) | VAF 14/57 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1299838441; called by muse, mutect2, varscan2
- AGFG2 | c.350C>T p.A117V | Missense Mutation (SNP) | VAF 13/53 reads (25%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.893); catalogued as rs755967504; called by muse, mutect2, varscan2
- AGO1 | c.263G>A p.R88H | Missense Mutation (SNP) | VAF 21/60 reads (35%) | SIFT tolerated (0.06); PolyPhen benign (0.157); catalogued as rs745615692, COSV64595185; called by muse, mutect2, varscan2
- AGO1 | c.1136G>A p.R379H | Missense Mutation (SNP) | VAF 5/13 reads (38%) | SIFT deleterious (0.05); PolyPhen benign (0.006); catalogued as COSV64595271; called by muse, mutect2, varscan2
- AGO2 | c.1756G>A p.V586M | Missense Mutation (SNP) | VAF 19/47 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.685); catalogued as rs1426022188; called by muse, mutect2, varscan2
- AGPAT1 | c.510C>T p.D170= | Splice Region (SNP) | VAF 12/42 reads (29%) | catalogued as COSV100421674; called by muse, varscan2
- AGPAT1 | c.451C>T p.R151C | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as rs1236603443, COSV61247029; called by muse, varscan2
- AGPAT4 | c.634G>A p.A212T | Missense Mutation (SNP) | VAF 23/60 reads (38%) | SIFT tolerated (1); PolyPhen benign (0.373); catalogued as rs1158616160, COSV57245733; called by muse, mutect2, varscan2
- AGPAT4 | c.239G>A p.R80H | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as rs773798140, COSV57245566; called by mutect2, varscan2
- AGPAT5 | c.347G>A p.R116H | Missense Mutation (SNP) | VAF 10/110 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as rs1469662784; called by muse, mutect2
- AHCY | c.101G>A p.R34H | Missense Mutation (SNP) | VAF 31/72 reads (43%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0); catalogued as rs775953872, COSV54152552; called by muse, mutect2, varscan2
- AHDC1 | c.419A>G p.H140R | Missense Mutation (SNP) | VAF 14/28 reads (50%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.059); catalogued as rs1376495214; called by muse, mutect2, varscan2
- AHNAK | c.13367C>T p.A4456V | Missense Mutation (SNP) | VAF 48/113 reads (42%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.62); catalogued as rs1159180489; called by muse, mutect2, varscan2
- AHNAK | c.3194C>A p.P1065H | Missense Mutation (SNP) | VAF 17/89 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV99948151; called by muse, mutect2, varscan2
- AHNAK2 | c.12766G>A p.V4256I | Missense Mutation (SNP) | VAF 18/130 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.026); catalogued as rs1354672144, COSV60909758, COSV60913985; called by muse, mutect2, varscan2
- AHRR | c.761C>T p.A254V | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT deleterious (0.04); PolyPhen benign (0.085); catalogued as rs373499533; called by muse, mutect2, varscan2
- AIPL1 | c.854C>T p.A285V | Missense Mutation (SNP) | VAF 24/89 reads (27%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.803); catalogued as rs148543951; called by muse, mutect2, varscan2
- AIPL1 | c.538G>A p.V180I | Missense Mutation (SNP) | VAF 18/54 reads (33%) | SIFT tolerated (0.48); PolyPhen benign (0.014); catalogued as rs761059176; ClinVar: uncertain significance; called by muse, varscan2
- AIPL1 | c.113G>A p.R38H | Missense Mutation (SNP) | VAF 19/49 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as rs759934433; called by muse, mutect2, varscan2
- AIRE | c.308-1G>T p.X103_splice | Splice Site (SNP) | VAF 8/44 reads (18%) | catalogued as COSV99381345; called by mutect2, varscan2
- AK4 | c.374G>A p.R125H | Missense Mutation (SNP) | VAF 13/78 reads (17%) | SIFT tolerated (0.08); PolyPhen benign (0.001); catalogued as rs142956995; called by muse, mutect2, varscan2
- AK5 | c.935G>A p.S312N (on ENST00000354567 / NM_174858.3; = p.S286N on NM_012093.4) | Missense Mutation (SNP) | VAF 20/58 reads (34%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.534); catalogued as COSV100642382; called by muse, mutect2, varscan2
- AK8 | c.267G>T p.E89D | Missense Mutation (SNP) | VAF 14/39 reads (36%) | SIFT tolerated (0.35); PolyPhen benign (0.01); catalogued as COSV53752896; called by muse, mutect2, varscan2
- AK9 | c.5456C>T p.A1819V | Missense Mutation (SNP) | VAF 18/78 reads (23%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs372465779, COSV69850596; called by muse, mutect2, varscan2
- AK9 | c.5309T>G p.F1770C | Missense Mutation (SNP) | VAF 12/31 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs1425980760, COSV69850255; called by muse, mutect2, varscan2
- AK9 | c.172C>T p.R58C | Missense Mutation (SNP) | VAF 18/58 reads (31%) | SIFT tolerated (0.2); PolyPhen benign (0.145); catalogued as rs775583178, COSV53423700, COSV99572572; called by muse, mutect2, varscan2
- AKAP10 | c.1250C>T p.S417F | Missense Mutation (SNP) | VAF 13/53 reads (25%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.891); catalogued as rs548243247; called by muse, mutect2, varscan2
- AKAP11 | c.1663G>A p.A555T | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT tolerated (1); PolyPhen benign (0.011); catalogued as rs1282666279; called by mutect2, varscan2
- AKAP11 | c.3013G>A p.D1005N | Missense Mutation (SNP) | VAF 21/44 reads (48%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.647); catalogued as rs138627318; called by muse, mutect2, varscan2
- AKAP13 | c.7600G>A p.A2534T (on ENST00000394518 / NM_007200.5; = p.A2538T on NM_006738.6) | Missense Mutation (SNP) | VAF 38/114 reads (33%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs754302898; called by muse, varscan2
- AKAP13 | c.7802G>A p.R2601H (on ENST00000394518 / NM_007200.5; = p.R2605H on NM_006738.6) | Missense Mutation (SNP) | VAF 18/56 reads (32%) | SIFT tolerated (0.05); PolyPhen benign (0.01); catalogued as rs369963716; called by muse, varscan2
- AKAP13 | c.7823G>A p.R2608H (on ENST00000394518 / NM_007200.5; = p.R2612H on NM_006738.6) | Missense Mutation (SNP) | VAF 10/56 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.893); catalogued as rs375611861; called by muse, varscan2
- AKAP3 | c.1673A>G p.N558S | Missense Mutation (SNP) | VAF 14/86 reads (16%) | SIFT tolerated (0.78); PolyPhen benign (0.019); catalogued as rs781317216; called by muse, varscan2
- AKAP4 | c.755G>A p.C252Y | Missense Mutation (SNP) | VAF 11/90 reads (12%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs781864742; called by muse, mutect2, varscan2
- AKAP8 | c.830G>A p.R277H | Missense Mutation (SNP) | VAF 12/64 reads (19%) | SIFT tolerated (0.26); PolyPhen benign (0.003); catalogued as rs776467913, COSV54103376; called by muse, varscan2
- AKAP8L | c.5G>A p.S2N | Missense Mutation (SNP) | VAF 45/154 reads (29%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.013); catalogued as COSV54608407; called by muse, mutect2, varscan2
- AKNA | c.3262C>T p.R1088C | Missense Mutation (SNP) | VAF 52/120 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as rs143050232; called by muse, mutect2, varscan2
- AKNAD1 | c.2047G>T p.E683* | Nonsense Mutation (SNP) | VAF 7/36 reads (19%) | catalogued as COSV62196232; called by muse, mutect2, varscan2
- AKR1B15 | c.205C>T p.R69C | Missense Mutation (SNP) | VAF 29/112 reads (26%) | SIFT tolerated (0.06); PolyPhen benign (0.1); catalogued as rs373511828; called by muse, mutect2, varscan2
- AKR1C2 | c.628G>T p.D210Y | Missense Mutation (SNP) | VAF 23/58 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs138437499; called by muse, mutect2, varscan2
- AKR1C4 | c.265T>C p.F89L | Missense Mutation (SNP) | VAF 7/68 reads (10%) | SIFT tolerated (0.08); PolyPhen benign (0.108); catalogued as COSV54123073; called by muse, mutect2
- AKR7A3 | c.62G>A p.R21H | Missense Mutation (SNP) | VAF 16/40 reads (40%) | SIFT deleterious (0.05); PolyPhen benign (0.023); catalogued as rs1242957830; called by muse, mutect2, varscan2
- AKR7L | c.409G>A p.V137M | Missense Mutation (SNP) | VAF 27/66 reads (41%) | SIFT tolerated (0.06); PolyPhen benign (0.04); catalogued as rs761826678; called by muse, mutect2, varscan2
- AKT2 | c.671G>A p.R224H | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT tolerated (0.16); PolyPhen benign (0.146); catalogued as rs746407532; called by mutect2, varscan2
- AL136295.1 | c.1637G>A p.R546H | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.391); catalogued as rs375173543; called by mutect2, varscan2
- ALB | c.80-1G>T p.X27_splice | Splice Site (SNP) | VAF 11/50 reads (22%) | catalogued as COSV55740158; called by muse, mutect2, varscan2
- ALDH1A2 | c.1007T>G p.F336C | Missense Mutation (SNP) | VAF 11/29 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV51090268; called by muse, mutect2, varscan2
- ALDH1L1 | c.1041C>A p.F347L | Missense Mutation (SNP) | VAF 12/51 reads (24%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (1); catalogued as rs1048277457, COSV99856448; called by muse, mutect2, varscan2
- ALDH3A2 | c.793G>A p.V265M | Missense Mutation (SNP) | VAF 7/46 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.786); catalogued as COSV51567398; called by muse, mutect2, varscan2
- ALDH4A1 | c.842G>A p.G281D | Missense Mutation (SNP) | VAF 18/62 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV99311974; called by muse, mutect2, varscan2
- ALDH5A1 | c.1540C>T p.R514* | Nonsense Mutation (SNP) | VAF 15/131 reads (11%) | catalogued as rs748170674, CM033327, COSV62373689; called by mutect2, varscan2
- ALDH7A1 | c.998C>T p.A333V | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT tolerated (0.06); PolyPhen benign (0.009); catalogued as rs144625212; ClinVar: uncertain significance; called by muse, varscan2
- ALDH8A1 | c.1289G>A p.R430H | Missense Mutation (SNP) | VAF 21/51 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs761930780, COSV55640296, COSV99039575; called by muse, mutect2, varscan2
- ALDH8A1 | c.151G>A p.V51I | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT tolerated (0.08); PolyPhen benign (0.395); catalogued as rs370946353; called by muse, mutect2, varscan2
- ALG2 | c.1151C>T p.A384V | Missense Mutation (SNP) | VAF 15/39 reads (38%) | SIFT tolerated (0.27); PolyPhen benign (0.005); catalogued as COSV99445381; called by muse, mutect2, varscan2
- ALG5 | c.289C>T p.R97* | Nonsense Mutation (SNP) | VAF 7/19 reads (37%) | catalogued as rs747848311, COSV99523651; called by muse, mutect2, varscan2
- ALMS1 | c.12040C>T p.R4014W | Missense Mutation (SNP) | VAF 8/43 reads (19%) | SIFT tolerated (0.15); PolyPhen benign (0.001); catalogued as rs543346172; called by muse, mutect2, varscan2
- ALOX12 | c.529A>G p.T177A | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT tolerated (0.12); PolyPhen benign (0.02); catalogued as COSV99277923; called by muse, mutect2, varscan2
- ALOX15B | c.2015A>G p.N672S | Missense Mutation (SNP) | VAF 20/70 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.356); catalogued as rs1398497554; called by muse, mutect2, varscan2
- ALOX5 | c.822G>T p.E274D | Missense Mutation (SNP) | VAF 27/133 reads (20%) | SIFT tolerated (0.15); PolyPhen benign (0.109); catalogued as COSV65553391; called by muse, mutect2, varscan2
- ALOX5 | c.880G>A p.D294N | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT tolerated (0.06); PolyPhen benign (0.057); catalogued as rs535808410, COSV65552256; called by muse, mutect2, varscan2
- ALPK1 | c.1229C>T p.S410F | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.24); catalogued as rs1170413588; called by muse, mutect2, varscan2
- ALPK2 | c.1157G>A p.R386Q | Missense Mutation (SNP) | VAF 12/69 reads (17%) | SIFT tolerated (0.47); PolyPhen benign (0); catalogued as rs764190677, COSV64489940; called by muse, varscan2
- ALPK3 | c.4177G>A p.A1393T | Missense Mutation (SNP) | VAF 16/40 reads (40%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.955); catalogued as COSV51936040; called by muse, mutect2, varscan2
- ALX4 | c.845G>A p.R282Q | Missense Mutation (SNP) | VAF 19/78 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.489); catalogued as rs144440589; called by muse, mutect2, varscan2
- AMBP | c.845G>A p.R282Q | Missense Mutation (SNP) | VAF 38/86 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs768762324; called by muse, mutect2, varscan2
- AMBRA1 | c.3749C>A p.S1250Y (on ENST00000458649 / NM_001367468.1; = p.S1160Y on NM_017749.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.006); catalogued as COSV54064076; called by muse, varscan2
- AMDHD1 | c.380G>A p.R127H | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT tolerated (0.06); PolyPhen benign (0.08); catalogued as rs779552415; called by mutect2, varscan2
- AMDHD2 | c.1018C>T p.R340W (on ENST00000293971 / NM_001330449.2; = p.R370W on NM_015944.4) | Missense Mutation (SNP) | VAF 4/17 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53550022; called by muse, mutect2
- AMER3 | c.952C>T p.R318C | Missense Mutation (SNP) | VAF 9/48 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.88); catalogued as rs113802956; called by mutect2, varscan2
- AMOTL2 | c.1105C>T p.R369C | Missense Mutation (SNP) | VAF 23/47 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs763829596, COSV51439293; called by muse, mutect2, varscan2
- AMOTL2 | c.89C>T p.T30M | Missense Mutation (SNP) | VAF 22/42 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as rs200336077, COSV99998178; called by muse, mutect2, varscan2
- AMY2B | c.175C>A p.P59T | Missense Mutation (SNP) | VAF 35/201 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV63714412; called by muse, mutect2, varscan2
- AMZ1 | c.622G>A p.A208T | Missense Mutation (SNP) | VAF 12/48 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as rs376694807, COSV56685496; called by muse, mutect2
- ANAPC1 | c.4919G>A p.G1640D | Missense Mutation (SNP) | VAF 14/144 reads (10%) | SIFT tolerated (0.55); PolyPhen benign (0.011); catalogued as rs533459247; called by mutect2, varscan2
- ANGPT4 | c.1505A>G p.D502G | Missense Mutation (SNP) | VAF 10/105 reads (10%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as COSV67921897; called by muse, mutect2, varscan2
- ANGPTL6 | c.629T>C p.V210A | Missense Mutation (SNP) | VAF 13/47 reads (28%) | SIFT tolerated (0.58); PolyPhen benign (0.019); catalogued as COSV99463452; called by muse, mutect2, varscan2
- ANK1 | c.867G>T p.E289D | Missense Mutation (SNP) | VAF 10/79 reads (13%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.682); catalogued as COSV99225714; called by muse, mutect2, varscan2
- ANK2 | c.10187C>A p.S3396Y | Missense Mutation (SNP) | VAF 10/20 reads (50%) | SIFT tolerated, low confidence (0.05); PolyPhen possibly damaging (0.542); catalogued as COSV100002141, COSV52184715; called by muse, mutect2, varscan2
- ANK2 | c.11378C>A p.S3793Y | Missense Mutation (SNP) | VAF 13/36 reads (36%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.613); catalogued as COSV52188723; called by muse, mutect2, varscan2
- ANK3 | c.3727C>T p.R1243C (on ENST00000280772 / NM_001320874.2; = p.R377C on NM_001149.3) | Missense Mutation (SNP) | VAF 29/77 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV55051776; called by muse, mutect2, varscan2
- ANK3 | c.674A>G p.D225G | Missense Mutation (SNP) | VAF 19/80 reads (24%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.977); catalogued as COSV55075296; called by muse, mutect2, varscan2
- ANKAR | c.2815G>A p.A939T | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT tolerated (0.05); PolyPhen benign (0.011); catalogued as rs747944684, COSV104385734; called by muse, mutect2, varscan2
- ANKFY1 | c.2737G>A p.A913T (on ENST00000341657 / NM_001330063.2; = p.A914T on NM_016376.5) | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1261557692, COSV100492162; called by muse, mutect2, varscan2
- ANKFY1 | c.2236C>T p.R746C (on ENST00000341657 / NM_001330063.2; = p.R747C on NM_016376.5) | Missense Mutation (SNP) | VAF 12/62 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs373777995; called by muse, mutect2, varscan2
- ANKFY1 | c.1337G>A p.R446H | Missense Mutation (SNP) | VAF 23/56 reads (41%) | SIFT tolerated (0.09); PolyPhen benign (0.019); catalogued as rs760240002; called by muse, mutect2, varscan2
- ANKIB1 | c.1972C>T p.R658C | Missense Mutation (SNP) | VAF 25/64 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs1221768191, COSV56065767; called by muse, mutect2, varscan2
- ANKMY2 | c.200G>A p.R67Q | Missense Mutation (SNP) | VAF 14/43 reads (33%) | SIFT tolerated (0.7); PolyPhen benign (0.01); catalogued as rs138949130; called by muse, mutect2, varscan2
- ANKRD10 | c.851T>C p.L284S | Missense Mutation (SNP) | VAF 8/41 reads (20%) | SIFT tolerated (0.12); PolyPhen benign (0.07); catalogued as rs1480110079; called by muse, mutect2, varscan2
- ANKRD11 | c.6823G>A p.A2275T | Missense Mutation (SNP) | VAF 4/8 reads (50%) | SIFT tolerated, low confidence (0.69); PolyPhen benign (0); catalogued as rs750990942, COSV56357132; called by muse, varscan2
- ANKRD11 | c.5498C>T p.A1833V | Missense Mutation (SNP) | VAF 7/48 reads (15%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as rs368237393; called by mutect2, varscan2
- ANKRD11 | c.5059G>T p.E1687* | Nonsense Mutation (SNP) | VAF 24/82 reads (29%) | catalogued as COSV56360009; called by muse, mutect2, varscan2
- ANKRD11 | c.196G>A p.A66T | Missense Mutation (SNP) | VAF 22/48 reads (46%) | SIFT tolerated (0.28); PolyPhen benign (0.066); catalogued as rs949172972, COSV56372489; called by muse, varscan2
- ANKRD17 | c.2236C>T p.R746C | Missense Mutation (SNP) | VAF 11/27 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV58219434; called by muse, mutect2, varscan2
- ANKRD2 | c.77C>T p.A26V | Missense Mutation (SNP) | VAF 37/113 reads (33%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.007); catalogued as rs773670423, COSV100081023; called by muse, mutect2, varscan2
- ANKRD22 | c.98A>C p.N33T | Missense Mutation (SNP) | VAF 32/94 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.518); catalogued as COSV64237236; called by muse, mutect2, varscan2
- ANKRD26 | c.689C>T p.S230F | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT tolerated (0.71); PolyPhen benign (0.005); catalogued as COSV100772696; called by muse, mutect2, varscan2
- ANKRD27 | c.2308G>A p.A770T | Missense Mutation (SNP) | VAF 19/68 reads (28%) | SIFT tolerated (0.08); PolyPhen benign (0.095); catalogued as rs1306229833, COSV100042633; called by muse, mutect2, varscan2
- ANKRD27 | c.1195G>A p.D399N | Missense Mutation (SNP) | VAF 17/65 reads (26%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.69); catalogued as rs185770739, COSV60130554; called by muse, mutect2, varscan2
- ANKRD27 | c.647T>C p.V216A | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.326); catalogued as COSV60134512; called by muse, mutect2, varscan2
- ANKRD28 | c.308G>A p.R103Q | Missense Mutation (SNP) | VAF 16/41 reads (39%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.899); catalogued as rs759510260; called by muse, mutect2, varscan2
- ANKRD28 | c.142G>A p.A48T | Missense Mutation (SNP) | VAF 11/63 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs746919799, COSV67520470; called by mutect2, varscan2
- ANKRD30A | c.622G>T p.A208S (on ENST00000611781; = p.A152S on NM_052997.2) | Missense Mutation (SNP) | VAF 13/112 reads (12%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.918); catalogued as COSV64616334; called by muse, varscan2
- ANKRD49 | c.655A>G p.T219A | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.046); catalogued as rs1249435869; called by muse, mutect2, varscan2
- ANKRD50 | c.3020C>T p.A1007V | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.61); catalogued as COSV72385619; called by muse, mutect2, varscan2
- ANKRD52 | c.2263C>T p.R755C | Missense Mutation (SNP) | VAF 25/61 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs1489734027, COSV57287498; called by muse, mutect2, varscan2
- ANKRD52 | c.1952G>A p.R651H | Missense Mutation (SNP) | VAF 7/52 reads (13%) | SIFT tolerated (0.26); PolyPhen benign (0.003); catalogued as rs757085023; called by mutect2, varscan2
- ANKRD52 | c.1456G>A p.D486N | Missense Mutation (SNP) | VAF 22/45 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as rs1368235699, COSV57285494; called by muse, mutect2, varscan2
- ANKRD54 | c.598G>A p.A200T | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT tolerated (0.41); PolyPhen possibly damaging (0.888); catalogued as rs1487344942; called by muse, varscan2
- ANKS3 | c.718G>A p.E240K | Missense Mutation (SNP) | VAF 9/22 reads (41%) | SIFT tolerated (0.07); PolyPhen benign (0.207); catalogued as rs142015202, COSV100423251; called by muse, mutect2, varscan2
- ANLN | c.1954C>T p.R652C | Missense Mutation (SNP) | VAF 22/42 reads (52%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.871); catalogued as rs569378477; called by muse, mutect2, varscan2
- ANO1 | c.952G>A p.D318N | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.545); catalogued as rs778292650; called by mutect2, varscan2
- ANO2 | c.1969G>A p.D657N (on ENST00000356134 / NM_001278597.3; = p.D661N on NM_001278596.3) | Missense Mutation (SNP) | VAF 18/42 reads (43%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs754933071, COSV59033341; called by muse, varscan2
- ANO3 | c.210A>G p.I70M | Missense Mutation (SNP) | VAF 7/51 reads (14%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.021); catalogued as COSV56780749; called by muse, mutect2, varscan2
- ANO3 | c.539G>A p.R180K | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.989); catalogued as COSV56784977; called by muse, mutect2, varscan2
- ANXA1 | c.403G>T p.D135Y | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV57412416; called by muse, mutect2, varscan2
- ANXA2 | c.373G>A p.E125K | Missense Mutation (SNP) | VAF 8/47 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.364); catalogued as COSV60318143; called by muse, mutect2
- ANXA7 | c.1375G>A p.A459T (on ENST00000372919 / NM_001320880.2; = p.A437T on NM_001156.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT tolerated (0.57); PolyPhen benign (0.022); catalogued as rs146521289; called by muse, mutect2, varscan2
- ANXA9 | c.625G>A p.A209T | Missense Mutation (SNP) | VAF 11/64 reads (17%) | SIFT tolerated (0.1); PolyPhen benign (0.001); catalogued as rs768715836; called by muse, mutect2, varscan2
- AOAH | c.1492C>A p.L498I | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.754); catalogued as COSV51735273, COSV99333536; called by mutect2, varscan2
- AOX1 | c.3061C>T p.R1021C | Missense Mutation (SNP) | VAF 26/71 reads (37%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.631); catalogued as rs774101325, COSV65984928; called by muse, mutect2, varscan2
- AP1AR | c.506G>A p.R169Q | Missense Mutation (SNP) | VAF 18/50 reads (36%) | SIFT tolerated (0.11); PolyPhen benign (0.127); catalogued as rs746050291, COSV56769706; called by muse, mutect2, varscan2
- AP1AR | c.673C>T p.R225C | Missense Mutation (SNP) | VAF 15/52 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.015); catalogued as COSV56768735; called by muse, mutect2, varscan2
- AP1G1 | c.2378G>A p.R793Q | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as COSV55486120; called by muse, mutect2, varscan2
- AP1G2 | c.1289C>T p.A430V | Missense Mutation (SNP) | VAF 28/84 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs752351764; called by muse, mutect2, varscan2
- AP1M1 | c.571C>T p.R191C | Missense Mutation (SNP) | VAF 56/152 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as rs780968690; called by muse, mutect2, varscan2
- AP3D1 | c.1591G>A p.A531T | Missense Mutation (SNP) | VAF 23/72 reads (32%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.49); catalogued as rs758018772, COSV61427494; called by muse, mutect2, varscan2
- AP3M2 | c.736C>T p.R246C | Missense Mutation (SNP) | VAF 24/75 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs748317550, COSV51527709; called by muse, varscan2
- AP4B1 | c.1057C>T p.R353* | Nonsense Mutation (SNP) | VAF 26/80 reads (33%) | catalogued as rs138335735; called by muse, mutect2, varscan2
- AP4B1 | c.902G>A p.R301H | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.931); catalogued as rs768636022, COSV99870972; called by mutect2, varscan2
- AP5B1 | c.1659G>T p.Q553H | Missense Mutation (SNP) | VAF 14/78 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.01); catalogued as COSV57502958; called by muse, mutect2, varscan2
- APBB1 | c.1958C>T p.A653V | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54967686; called by muse, mutect2, varscan2
- APBB1 | c.1513G>A p.E505K | Missense Mutation (SNP) | VAF 7/51 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.424); catalogued as rs754789288, COSV54981346; called by mutect2, varscan2
- APC | c.680A>G p.D227G | Missense Mutation (SNP) | VAF 5/54 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.615); catalogued as rs975710261, COSV57373496; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- APC | c.5264C>T p.A1755V | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs771967537, COSV57385301; ClinVar: likely benign / uncertain significance; called by muse, varscan2
- APC2 | c.1162C>A p.L388M | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT tolerated (0.16); PolyPhen benign (0.11); catalogued as rs868433466; called by muse, mutect2
- APCDD1L | c.736G>A p.A246T | Missense Mutation (SNP) | VAF 4/23 reads (17%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.736); catalogued as rs1459187259; called by muse, mutect2
- APEH | c.184C>T p.R62* | Nonsense Mutation (SNP) | VAF 32/76 reads (42%) | catalogued as rs577640330, COSV56517850; called by muse, mutect2, varscan2
- APLP1 | c.1105C>T p.R369* | Nonsense Mutation (SNP) | VAF 9/41 reads (22%) | catalogued as COSV99697631; called by muse, mutect2, varscan2
- APOA4 | c.751G>A p.E251K | Missense Mutation (SNP) | VAF 13/31 reads (42%) | SIFT deleterious (0.03); PolyPhen benign (0.105); catalogued as COSV63360489; called by muse, mutect2, varscan2
- APOA4 | c.415G>A p.A139T | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT tolerated (0.21); PolyPhen benign (0.114); catalogued as rs1320283776, COSV63361154; called by muse, mutect2
- APOBEC1 | c.582G>T p.K194N | Missense Mutation (SNP) | VAF 12/57 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.005); catalogued as COSV57549020, COSV57550510; called by muse, mutect2, varscan2
- APOBEC3D | c.31C>T p.R11W | Missense Mutation (SNP) | VAF 23/83 reads (28%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.893); catalogued as rs1329417586; called by muse, mutect2, varscan2
- APOL1 | c.95C>T p.A32V | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0); catalogued as rs753380461, COSV59869114; called by muse, mutect2, varscan2
- APP | c.1462C>T p.R488C | Missense Mutation (SNP) | VAF 15/63 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV60994141; called by muse, mutect2, varscan2
- APPBP2 | c.848A>C p.K283T | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.775); catalogued as rs748159221; called by muse, mutect2, varscan2
- APPL1 | c.608A>G p.Y203C | Missense Mutation (SNP) | VAF 11/30 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.868); catalogued as rs771643634; called by muse, mutect2, varscan2
- AQP12A | c.46G>A p.A16T | Missense Mutation (SNP) | VAF 6/49 reads (12%) | SIFT tolerated (0.19); PolyPhen benign (0.005); catalogued as rs566667626; called by mutect2, varscan2
- AQP12A | c.337G>A p.A113T | Missense Mutation (SNP) | VAF 6/43 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.85); catalogued as rs775028865, COSV61837886; called by mutect2, varscan2
- AQP4 | c.647G>A p.R216Q | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs777406434, COSV67218560; called by muse, mutect2, varscan2
- AQP6 | c.751G>T p.G251C | Missense Mutation (SNP) | VAF 27/94 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59646687; called by muse, mutect2, varscan2
- AQR | c.3352T>C p.S1118P | Missense Mutation (SNP) | VAF 5/51 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.712); catalogued as COSV50033137; called by muse, mutect2, varscan2
- AQR | c.998G>A p.R333K | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT tolerated (0.62); PolyPhen benign (0.001); catalogued as COSV50035895; called by mutect2, varscan2
- ARAF | c.632G>A p.R211H | Missense Mutation (SNP) | VAF 43/138 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs923182352, COSV99283155; called by muse, mutect2, varscan2
- ARAF | c.794C>T p.S265L | Missense Mutation (SNP) | VAF 11/55 reads (20%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as rs1229309673; called by muse, mutect2, varscan2
- ARAP1 | c.3217C>T p.R1073W (on ENST00000393609 / NM_001040118.2; = p.R828W on NM_015242.4) | Missense Mutation (SNP) | VAF 9/49 reads (18%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.773); catalogued as rs139658168; called by mutect2, varscan2
- ARAP2 | c.4063G>A p.E1355K | Missense Mutation (SNP) | VAF 7/37 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs1560459149; called by muse, mutect2, varscan2
- ARAP3 | c.3301G>A p.E1101K | Missense Mutation (SNP) | VAF 26/63 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV53354844; called by muse, mutect2, varscan2
- ARAP3 | c.2953C>T p.R985C | Missense Mutation (SNP) | VAF 20/52 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs866209168, COSV53351227; called by muse, varscan2
- ARFGEF1 | c.5101G>A p.E1701K | Missense Mutation (SNP) | VAF 16/43 reads (37%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.893); catalogued as rs771330319; called by muse, mutect2, varscan2
- ARFGEF1 | c.4247G>A p.G1416D | Missense Mutation (SNP) | VAF 13/50 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51614578; called by muse, mutect2, varscan2
- ARFGEF2 | c.4210C>T p.H1404Y | Missense Mutation (SNP) | VAF 36/98 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64210640; called by muse, mutect2, varscan2
- ARFGEF3 | c.1046G>A p.R349Q | Missense Mutation (SNP) | VAF 14/41 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.296); catalogued as rs761083705; called by muse, varscan2
- ARFGEF3 | c.2803G>A p.A935T | Missense Mutation (SNP) | VAF 15/59 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs768653939, COSV99294457; called by muse, mutect2, varscan2
- ARFIP1 | c.910T>C p.Y304H (on ENST00000353617 / NM_001287432.1; = p.Y272H on NM_014447.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 13/24 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1295340011; called by muse, mutect2, varscan2
- ARG2 | c.754A>G p.I252V | Missense Mutation (SNP) | VAF 5/38 reads (13%) | SIFT tolerated (0.73); PolyPhen benign (0.29); catalogued as COSV99373851; called by muse, mutect2
- ARHGAP12 | c.2158T>C p.W720R | Missense Mutation (SNP) | VAF 14/29 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100261023; called by muse, mutect2, varscan2
- ARHGAP18 | c.1312G>A p.A438T | Missense Mutation (SNP) | VAF 13/34 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.838); catalogued as rs917705561; called by muse, mutect2, varscan2
- ARHGAP18 | c.1022G>A p.R341Q | Missense Mutation (SNP) | VAF 17/59 reads (29%) | SIFT tolerated (0.06); PolyPhen benign (0.011); catalogued as rs539196958, COSV63765384; called by muse, mutect2, varscan2
- ARHGAP18 | c.495G>T p.Q165H | Missense Mutation (SNP) | VAF 19/81 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.039); catalogued as rs11544372; called by muse, mutect2, varscan2
- ARHGAP19 | c.985G>A p.A329T | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT tolerated (0.57); PolyPhen benign (0.001); catalogued as COSV57391470; called by muse, mutect2
- ARHGAP21 | c.1661G>A p.R554Q | Missense Mutation (SNP) | VAF 14/110 reads (13%) | SIFT tolerated (0.32); PolyPhen benign (0.177); catalogued as rs749708727, COSV57608438; called by mutect2, varscan2
- ARHGAP22 | c.1841G>A p.R614Q | Missense Mutation (SNP) | VAF 26/125 reads (21%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.616); catalogued as COSV50957442; called by muse, mutect2, varscan2
- ARHGAP22 | c.1714G>A p.E572K | Missense Mutation (SNP) | VAF 13/66 reads (20%) | SIFT tolerated (0.38); PolyPhen benign (0.033); catalogued as rs774629741; called by muse, mutect2, varscan2
- ARHGAP24 | c.1212G>T p.K404N (on ENST00000395184 / NM_001025616.3; = p.K311N on NM_031305.3) | Missense Mutation (SNP) | VAF 15/48 reads (31%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as COSV51988069; called by muse, mutect2, varscan2
- ARHGAP25 | c.640G>A p.A214T (on ENST00000409202 / NM_001007231.3; = p.A206T on NM_014882.3) | Missense Mutation (SNP) | VAF 28/69 reads (41%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.937); catalogued as rs769047657; called by muse, mutect2, varscan2
- ARHGAP30 | c.46C>T p.R16W | Missense Mutation (SNP) | VAF 34/80 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs1233696220, COSV100919988; called by muse, mutect2, varscan2
- ARHGAP33 | c.520C>T p.R174* | Nonsense Mutation (SNP) | VAF 25/60 reads (42%) | catalogued as COSV99138275; called by muse, mutect2, varscan2
- ARHGAP35 | c.622C>T p.R208W | Missense Mutation (SNP) | VAF 10/54 reads (19%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.972); catalogued as rs1388882878; called by muse, mutect2, varscan2
- ARHGAP35 | c.3440G>A p.R1147H | Missense Mutation (SNP) | VAF 8/60 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.929); catalogued as COSV68330597; called by mutect2, varscan2
- ARHGAP36 | c.848A>G p.D283G | Missense Mutation (SNP) | VAF 9/40 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.533); catalogued as rs1286277183; called by muse, mutect2, varscan2
- ARHGAP5 | c.194G>A p.R65Q | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs373505990; called by mutect2, varscan2
- ARHGAP6 | c.629G>A p.R210Q | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT tolerated (0.17); PolyPhen benign (0.099); catalogued as rs749408255; called by mutect2, varscan2
- ARHGAP9 | c.1793C>T p.A598V (on ENST00000393797 / NM_001319850.2; = p.A579V on NM_032496.4) | Missense Mutation (SNP) | VAF 11/59 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.272); catalogued as rs1359812172; called by muse, mutect2, varscan2
- ARHGEF10 | c.316A>G p.K106E (on ENST00000398564; = p.K82E on NM_014629.4) | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0.026); catalogued as rs1311683805; called by muse, mutect2, varscan2
- ARHGEF10 | c.649G>A p.A217T (on ENST00000398564; = p.A192T on NM_014629.4) | Missense Mutation (SNP) | VAF 5/30 reads (17%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.012); catalogued as rs779899466, COSV50649026; called by muse, mutect2, varscan2
- ARHGEF10 | c.1130C>T p.T377I (on ENST00000398564; = p.T352I on NM_014629.4) | Missense Mutation (SNP) | VAF 30/85 reads (35%) | SIFT tolerated (0.07); PolyPhen benign (0.408); catalogued as rs1371554243; called by muse, varscan2
- ARHGEF10L | c.142G>A p.A48T | Missense Mutation (SNP) | VAF 13/43 reads (30%) | SIFT tolerated, low confidence (0.52); PolyPhen benign (0.001); catalogued as rs138712645; called by muse, mutect2, varscan2
- ARHGEF10L | c.580G>A p.A194T | Missense Mutation (SNP) | VAF 7/13 reads (54%) | SIFT tolerated (0.48); PolyPhen benign (0.005); catalogued as rs879470657; called by muse, mutect2, varscan2
- ARHGEF10L | c.1028G>A p.R343H | Missense Mutation (SNP) | VAF 7/44 reads (16%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.969); catalogued as rs145122943, COSV51433371; called by mutect2, varscan2
- ARHGEF10L | c.3695G>A p.R1232H | Missense Mutation (SNP) | VAF 11/58 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs748630782, COSV51431481; called by muse, mutect2, varscan2
- ARHGEF11 | c.217C>T p.R73W | Missense Mutation (SNP) | VAF 19/52 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs142608371; called by muse, mutect2, varscan2
- ARHGEF11 | c.104C>T p.S35L | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.061); catalogued as rs375264879; called by muse, mutect2, varscan2
- ARHGEF15 | c.712C>T p.P238S | Missense Mutation (SNP) | VAF 35/80 reads (44%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.096); catalogued as rs778880579; called by muse, mutect2, varscan2
- ARHGEF15 | c.1676G>A p.R559H | Missense Mutation (SNP) | VAF 10/54 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs866909786, COSV62724502; called by muse, mutect2, varscan2
- ARHGEF17 | c.3496G>A p.D1166N | Missense Mutation (SNP) | VAF 22/77 reads (29%) | SIFT tolerated (0.44); PolyPhen probably damaging (0.946); catalogued as rs780905191, COSV55230187; called by muse, mutect2, varscan2
- ARHGEF18 | c.1451C>A p.S484Y (on ENST00000359920 / NM_001130955.2; = p.S380Y on NM_015318.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 18/54 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs999889638; called by muse, varscan2
- ARHGEF2 | c.950G>A p.R317H (on ENST00000361247 / NM_001162383.2; = p.R289H on NM_004723.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 19/55 reads (35%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.756); catalogued as rs550963600; called by muse, mutect2, varscan2
- ARHGEF26 | c.1435G>A p.E479K | Missense Mutation (SNP) | VAF 27/62 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); catalogued as rs1326384789; called by muse, mutect2, varscan2
- ARHGEF26 | c.1899G>A p.M633I | Missense Mutation (SNP) | VAF 34/101 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.292); catalogued as rs202135882; called by muse, mutect2, varscan2
- ARHGEF28 | c.4847C>A p.P1616H | Missense Mutation (SNP) | VAF 21/56 reads (38%) | SIFT tolerated (0.5); PolyPhen benign (0.101); catalogued as COSV99708563; called by muse, mutect2, varscan2
- ARHGEF4 | c.422G>A p.G141D | Missense Mutation (SNP) | VAF 23/90 reads (26%) | SIFT tolerated (0.61); PolyPhen benign (0); catalogued as rs767788213, COSV58130201; called by muse, mutect2, varscan2
- ARHGEF40 | c.1150C>T p.R384* | Nonsense Mutation (SNP) | VAF 3/17 reads (18%) | catalogued as rs1442827126, COSV100070739; called by muse, mutect2
- ARID1A | c.3316A>G p.K1106E | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.984); catalogued as COSV61383870; called by muse, mutect2, varscan2
- ARID1B | c.4202C>T p.P1401L | Missense Mutation (SNP) | VAF 6/45 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.161); catalogued as rs530430137; ClinVar: uncertain significance; called by mutect2, varscan2
- ARID1B | c.4516C>T p.R1506C | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.869); catalogued as rs1285642669, COSV51676869; called by muse, mutect2, varscan2
- ARID4A | c.1267G>A p.D423N | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT tolerated (0.2); PolyPhen benign (0.014); catalogued as rs201870686; called by muse, mutect2, varscan2
- ARIH1 | c.963G>T p.K321N | Missense Mutation (SNP) | VAF 11/42 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.928); catalogued as rs1320295436, COSV101158871, COSV65911009; called by muse, mutect2, varscan2
- ARL13B | c.665G>A p.R222Q (on ENST00000394222 / NM_001174150.2; = p.R115Q on NM_144996.4) | Missense Mutation (SNP) | VAF 14/27 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as rs1478163991, COSV100115133; called by muse, mutect2, varscan2
- ARL14EP | c.706C>T p.R236C | Missense Mutation (SNP) | VAF 26/91 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV56343585; called by muse, mutect2, varscan2
- ARMC1 | c.191G>A p.R64Q | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT tolerated (0.14); PolyPhen benign (0.093); catalogued as rs778463803; called by muse, mutect2, varscan2
- ARMC6 | c.613G>A p.A205T (on ENST00000392336; = p.A180T on NM_033415.4) | Missense Mutation (SNP) | VAF 15/43 reads (35%) | SIFT tolerated (0.31); PolyPhen benign (0.029); catalogued as rs201134374; called by muse, mutect2, varscan2
- ARMC9 | c.1865C>T p.T622M | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.428); catalogued as rs749948079; called by muse, varscan2
- ARMCX5-GPRASP2 | c.400A>G p.S134G | Missense Mutation (SNP) | VAF 26/58 reads (45%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as rs371712485; called by muse, mutect2, varscan2
- ARMH4 | c.232T>C p.S78P | Missense Mutation (SNP) | VAF 38/108 reads (35%) | SIFT tolerated (0.28); PolyPhen benign (0.009); catalogued as COSV50765422, COSV50766069; called by muse, mutect2, varscan2
- ARSB | c.1033C>T p.R345W | Missense Mutation (SNP) | VAF 12/23 reads (52%) | SIFT tolerated (0.06); PolyPhen benign (0.105); catalogued as rs780380678; called by muse, mutect2, varscan2
- ARSD | c.762G>T p.W254C | Missense Mutation (SNP) | VAF 15/46 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs757618990; called by muse, mutect2, varscan2
- ARSI | c.574G>A p.D192N | Missense Mutation (SNP) | VAF 16/56 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs746240121, COSV60816590; called by muse, mutect2, varscan2
- ARSK | c.1289C>T p.S430L | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT tolerated (0.05); PolyPhen benign (0.136); catalogued as rs763396857, COSV66169295; called by muse, varscan2
- ARSL | c.1525G>A p.D509N | Missense Mutation (SNP) | VAF 17/97 reads (18%) | SIFT tolerated (0.21); PolyPhen benign (0.023); catalogued as rs772908873; called by muse, mutect2, varscan2
- ARSL | c.898G>A p.V300I | Missense Mutation (SNP) | VAF 16/52 reads (31%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.493); catalogued as rs752354785, COSV66965067; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ART3 | c.642T>G p.F214L | Missense Mutation (SNP) | VAF 11/31 reads (35%) | SIFT tolerated (0.21); PolyPhen benign (0.057); catalogued as rs754733681; called by muse, varscan2
- ASAP3 | c.2128C>T p.R710C | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT tolerated (0.18); PolyPhen benign (0.183); catalogued as rs147016526; called by muse, mutect2, varscan2
- ASB1 | c.431G>A p.R144H | Missense Mutation (SNP) | VAF 21/69 reads (30%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.999); catalogued as rs766226125, COSV99223479; called by muse, mutect2, varscan2
- ASB10 | c.793G>A p.D265N (on ENST00000420175 / NM_001142459.2; = p.D250N on NM_080871.4) | Missense Mutation (SNP) | VAF 8/58 reads (14%) | SIFT tolerated (0.07); PolyPhen benign (0.007); catalogued as rs200652340; called by mutect2, varscan2
- ASB11 | c.828G>T p.Q276H | Missense Mutation (SNP) | VAF 9/77 reads (12%) | SIFT deleterious (0.05); PolyPhen benign (0.085); catalogued as COSV100729075; called by muse, mutect2, varscan2
- ASB12 | c.174G>T p.E58D | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT tolerated (0.44); PolyPhen benign (0.019); catalogued as COSV62857081; called by muse, mutect2, varscan2
- ASB14 | c.1345C>T p.R449* | Nonsense Mutation (SNP) | VAF 17/34 reads (50%) | catalogued as rs570963427; called by muse, mutect2, varscan2
- ASB2 | c.1172G>A p.R391H | Missense Mutation (SNP) | VAF 12/68 reads (18%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.564); catalogued as COSV60110759; called by muse, mutect2, varscan2
- ASB2 | c.292G>A p.A98T | Missense Mutation (SNP) | VAF 8/54 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as rs200689971, COSV60112158, COSV60114316; called by muse, varscan2
- ASCC2 | c.2092G>A p.A698T | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as rs761002921, COSV57076574; called by muse, mutect2, varscan2
- ASCC3 | c.5020C>T p.R1674C | Missense Mutation (SNP) | VAF 23/66 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs112466876, COSV100976363; called by muse, mutect2, varscan2
- ASIC3 | c.738G>T p.E246D | Missense Mutation (SNP) | VAF 5/61 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV52505698, COSV99874966; called by muse, mutect2
- ASPDH | c.761C>T p.A254V (on ENST00000389208 / NM_001114598.2; = p.A149V on NM_001024656.3) | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT tolerated (0.09); PolyPhen benign (0.175); catalogued as COSV65349469; called by muse, varscan2
- ASPHD2 | c.406C>T p.R136C | Missense Mutation (SNP) | VAF 20/55 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1328461360; called by muse, varscan2
- ASPM | c.9542G>A p.R3181Q | Missense Mutation (SNP) | VAF 10/52 reads (19%) | SIFT tolerated (0.47); PolyPhen benign (0.021); catalogued as rs1317628872, COSV99661009; called by mutect2, varscan2
- ASPM | c.8557C>T p.R2853W | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs150424130; ClinVar: uncertain significance; called by muse, varscan2
- ASPM | c.4495C>T p.R1499W | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs756067585, COSV54125044; called by mutect2, varscan2
- ASPM | c.2377C>T p.R793W | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs779018406, COSV54127872; called by mutect2, varscan2
- ASPM | c.1304C>T p.S435L | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT tolerated (1); PolyPhen benign (0.121); catalogued as rs150684410; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ASTN1 | c.2345C>T p.S782L | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as rs775289022, COSV56089550, COSV99920691; called by muse, mutect2, varscan2
- ASTN2 | c.2927G>A p.R976H (on ENST00000313400 / NM_001365069.1; = p.R925H on NM_014010.5) | Missense Mutation (SNP) | VAF 17/49 reads (35%) | SIFT tolerated (0.23); PolyPhen benign (0.003); catalogued as rs148503875; called by muse, mutect2, varscan2
- ASXL1 | c.1609G>A p.E537K | Missense Mutation (SNP) | VAF 14/52 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs369425922, COSV60104004, COSV60108838; called by muse, mutect2, varscan2
- ASXL1 | c.1836G>T p.R612S | Missense Mutation (SNP) | VAF 28/79 reads (35%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.783); catalogued as rs1224237404, COSV60124612; called by muse, mutect2, varscan2
- ASXL3 | c.1067G>T p.R356M | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV52479699; called by muse, mutect2, varscan2
- ASXL3 | c.2350G>T p.D784Y | Missense Mutation (SNP) | VAF 9/20 reads (45%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.733); catalogued as COSV52461560; called by muse, mutect2, varscan2
- ASZ1 | c.1363G>T p.A455S | Missense Mutation (SNP) | VAF 23/72 reads (32%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.556); catalogued as COSV99497648; called by muse, mutect2, varscan2
- ATAD2 | c.1541G>A p.R514Q | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs151296109; called by muse, mutect2, varscan2
- ATAD2B | c.617G>A p.R206Q | Missense Mutation (SNP) | VAF 17/59 reads (29%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.939); catalogued as rs1409404915, COSV53201278; called by muse, mutect2, varscan2
- ATF3 | c.274C>T p.R92* | Nonsense Mutation (SNP) | VAF 11/27 reads (41%) | catalogued as rs756952643, COSV58378340; called by muse, varscan2
- ATF6 | c.304G>T p.V102F | Missense Mutation (SNP) | VAF 23/65 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.578); catalogued as COSV63407306; called by muse, mutect2, varscan2
- ATF7IP2 | c.110C>T p.A37V | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT tolerated (0.29); PolyPhen benign (0.142); catalogued as rs758481978; called by mutect2, varscan2
- ATG2A | c.4696G>A p.A1566T | Missense Mutation (SNP) | VAF 12/47 reads (26%) | SIFT tolerated (0.23); PolyPhen benign (0.024); catalogued as rs1193391056; called by muse, mutect2, varscan2
- ATG2B | c.1094G>A p.R365Q | Missense Mutation (SNP) | VAF 17/58 reads (29%) | SIFT tolerated (0.26); PolyPhen benign (0.357); catalogued as rs778368919, COSV100737778, COSV63421927; called by muse, mutect2, varscan2
- ATG7 | c.1931A>G p.D644G | Missense Mutation (SNP) | VAF 27/76 reads (36%) | SIFT deleterious (0.03); PolyPhen benign (0.421); catalogued as rs753808883; called by muse, mutect2, varscan2
- ATG9A | c.1384C>T p.R462W | Missense Mutation (SNP) | VAF 8/51 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1041538685, COSV54699654; called by muse, mutect2, varscan2
- ATM | c.3232C>A p.L1078I | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV53742973; called by muse, mutect2, varscan2
- ATP10A | c.2426G>A p.R809H | Missense Mutation (SNP) | VAF 28/71 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs776829827, COSV63516508, COSV63516647, COSV63518546; called by muse, mutect2, varscan2
- ATP10B | c.982T>C p.C328R | Missense Mutation (SNP) | VAF 25/73 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.906); catalogued as rs1223854633; called by muse, mutect2, varscan2
- ATP10D | c.2234G>A p.R745Q | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT tolerated (0.29); PolyPhen benign (0.003); catalogued as rs1162198061, COSV99905450; called by muse, mutect2, varscan2
- ATP10D | c.2735C>T p.A912V | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs200004371; called by muse, varscan2
- ATP11A | c.1820G>A p.R607Q | Missense Mutation (SNP) | VAF 14/75 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs745652275; called by muse, mutect2, varscan2
- ATP11B | c.3171G>T p.Q1057H | Missense Mutation (SNP) | VAF 8/72 reads (11%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.94); catalogued as COSV60026354; called by mutect2, varscan2
- ATP11C | c.2980G>A p.G994R | Missense Mutation (SNP) | VAF 14/126 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV59567552; called by muse, varscan2
- ATP12A | c.551C>A p.A184D | Missense Mutation (SNP) | VAF 13/75 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as rs1459186112; called by muse, mutect2, varscan2
- ATP12A | c.2687G>A p.R896H | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as rs756031037, COSV54518726; called by muse, mutect2, varscan2
- ATP13A4 | c.3166T>C p.F1056L | Missense Mutation (SNP) | VAF 29/107 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.615); catalogued as rs866824230; called by muse, mutect2, varscan2
- ATP1A1 | c.280C>T p.R94W | Missense Mutation (SNP) | VAF 34/92 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.894); catalogued as rs1159259511; called by muse, mutect2, varscan2
- ATP1A3 | c.2516C>T p.P839L (on ENST00000545399 / NM_001256214.2; = p.P826L on NM_152296.5) | Missense Mutation (SNP) | VAF 12/41 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57485014; called by muse, mutect2, varscan2
- ATP1A4 | c.148-1G>T p.X50_splice | Splice Site (SNP) | VAF 20/61 reads (33%) | catalogued as COSV100927651; called by muse, mutect2, varscan2
- ATP1A4 | c.1157C>T p.T386M | Missense Mutation (SNP) | VAF 14/108 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs755503610, COSV63625336; called by muse, mutect2, varscan2
- ATP1B2 | c.796G>A p.A266T | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT tolerated (0.16); PolyPhen benign (0.025); catalogued as rs1321470106, COSV51516349; called by muse, mutect2, varscan2
- ATP2A1 | c.499G>A p.A167T | Missense Mutation (SNP) | VAF 8/54 reads (15%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as rs757752844, COSV63920538; called by mutect2, varscan2
- ATP2B1 | c.2536C>T p.R846* | Nonsense Mutation (SNP) | VAF 9/42 reads (21%) | catalogued as COSV53805755, COSV53811872; called by muse, mutect2, varscan2
- ATP2B2 | c.3007C>T p.R1003C (on ENST00000352432; = p.R969C on NM_001683.5) | Missense Mutation (SNP) | VAF 30/96 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100659613; called by muse, mutect2, varscan2
- ATP2B3 | c.1879C>T p.R627W | Missense Mutation (SNP) | VAF 34/92 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as rs1557012168; called by muse, varscan2
- ATP2B4 | c.2823C>A p.F941L | Missense Mutation (SNP) | VAF 16/52 reads (31%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs752873394, COSV58176270; called by muse, mutect2, varscan2
- ATP2C2 | c.2107G>A p.A703T | Missense Mutation (SNP) | VAF 15/53 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.84); catalogued as rs201597906; called by muse, mutect2, varscan2
- ATP4A | c.2003G>A p.R668H | Missense Mutation (SNP) | VAF 7/44 reads (16%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.553); catalogued as rs145767701, COSV52866100; called by mutect2, varscan2
- ATP4A | c.1903G>A p.A635T | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1404726499; called by muse, mutect2, varscan2
- ATP4A | c.1358T>C p.V453A | Missense Mutation (SNP) | VAF 6/49 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.243); catalogued as rs1457146122; called by muse, mutect2, varscan2
- ATP6AP1 | c.188C>T p.T63I | Missense Mutation (SNP) | VAF 46/127 reads (36%) | SIFT tolerated (0.17); PolyPhen benign (0.011); catalogued as COSV62341150; called by muse, mutect2, varscan2
- ATP6V0A1 | c.536G>A p.R179H | Missense Mutation (SNP) | VAF 38/115 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs565034112, COSV52872300; called by muse, mutect2, varscan2
- ATP6V0A4 | c.1825G>A p.A609T | Missense Mutation (SNP) | VAF 6/45 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs760974203; called by mutect2, varscan2
- ATP6V1E2 | c.236C>T p.A79V | Missense Mutation (SNP) | VAF 31/89 reads (35%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.466); catalogued as rs549725173; called by muse, mutect2, varscan2
- ATP6V1H | c.871-1G>T p.X291_splice | Splice Site (SNP) | VAF 6/27 reads (22%) | catalogued as COSV62219279; called by muse, mutect2, varscan2
- ATP6V1H | c.785G>A p.R262H | Missense Mutation (SNP) | VAF 11/43 reads (26%) | SIFT tolerated (0.13); PolyPhen benign (0.014); catalogued as rs200328593, COSV62219610; called by muse, mutect2, varscan2
- ATP7A | c.911A>G p.Y304C | Missense Mutation (SNP) | VAF 10/50 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.003); catalogued as rs1557231810; called by muse, mutect2, varscan2
- ATP7A | c.3592G>A p.D1198N | Missense Mutation (SNP) | VAF 21/72 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.001); catalogued as rs1374099672; called by muse, mutect2, varscan2
- ATP8A1 | c.1814G>T p.R605I | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.967); catalogued as COSV52552404; called by muse, mutect2, varscan2
- ATP8B2 | c.540G>A p.A180= (on ENST00000672630; = p.A147= on NM_001005855.2) | Splice Region (SNP) | VAF 29/112 reads (26%) | catalogued as rs1186331733; called by muse, mutect2, varscan2
- ATP9B | c.2566C>T p.R856C | Missense Mutation (SNP) | VAF 20/49 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.601); catalogued as rs200790686, COSV100303105; called by muse, mutect2, varscan2
- ATP9B | c.2792T>C p.L931P | Missense Mutation (SNP) | VAF 15/51 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as rs1265754356; called by muse, mutect2, varscan2
- ATR | c.6307G>A p.E2103K | Missense Mutation (SNP) | VAF 11/46 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.075); catalogued as COSV100638298; called by muse, mutect2, varscan2
- ATRNL1 | c.737T>C p.I246T | Missense Mutation (SNP) | VAF 14/64 reads (22%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.966); catalogued as rs1034900184; called by muse, mutect2, varscan2
- ATRX | c.6485T>C p.V2162A | Missense Mutation (SNP) | VAF 12/93 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV64880129; called by muse, mutect2
- ATXN2L | c.868C>T p.R290C | Missense Mutation (SNP) | VAF 11/50 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs759450724, COSV57368378; called by muse, mutect2, varscan2
- ATXN7 | c.818C>T p.A273V | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT tolerated (0.3); PolyPhen benign (0.003); catalogued as rs369372603; called by mutect2, varscan2
- AUP1 | c.829C>T p.R277C | Missense Mutation (SNP) | VAF 7/15 reads (47%) | SIFT tolerated (0.18); PolyPhen benign (0.169); catalogued as rs757009295, COSV51212038; called by muse, mutect2, varscan2
- AURKC | c.230C>T p.S77L (on ENST00000302804 / NM_001015878.2; = p.S43L on NM_003160.3) | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.43); catalogued as COSV57137280; called by muse, varscan2
- AVIL | c.1291G>A p.E431K | Missense Mutation (SNP) | VAF 14/35 reads (40%) | SIFT tolerated (0.83); PolyPhen benign (0.005); catalogued as rs142455344; called by muse, mutect2, varscan2
- AVL9 | c.1487C>T p.T496M | Missense Mutation (SNP) | VAF 33/79 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs141983074; called by muse, mutect2, varscan2
- AXDND1 | c.2768C>T p.A923V | Missense Mutation (SNP) | VAF 20/42 reads (48%) | SIFT deleterious (0.02); PolyPhen benign (0.058); catalogued as rs1485911318; called by muse, mutect2, varscan2
- AXIN1 | c.893G>A p.R298Q | Missense Mutation (SNP) | VAF 17/46 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.714); catalogued as COSV51990834; called by muse, mutect2, varscan2
- B3GLCT | c.1324C>T p.H442Y | Missense Mutation (SNP) | VAF 12/81 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.863); catalogued as rs376395941, COSV100587093; called by mutect2, varscan2
- B3GNT3 | c.193A>G p.T65A | Missense Mutation (SNP) | VAF 17/59 reads (29%) | SIFT tolerated (0.68); PolyPhen benign (0.001); catalogued as COSV59437370; called by muse, varscan2
- B3GNT3 | c.260G>A p.R87K | Missense Mutation (SNP) | VAF 22/81 reads (27%) | SIFT tolerated (0.56); PolyPhen benign (0.009); catalogued as rs868044165; called by muse, varscan2
- B3GNT7 | c.556C>T p.R186C | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.912); catalogued as rs768768447; called by mutect2, varscan2
- B3GNT8 | c.325G>A p.A109T | Missense Mutation (SNP) | VAF 5/37 reads (14%) | SIFT tolerated (0.68); PolyPhen benign (0); catalogued as rs759971616; called by mutect2, varscan2
- B4GALNT4 | c.2718C>T p.D906= | Splice Region (SNP) | VAF 7/44 reads (16%) | catalogued as rs779994504, COSV57321550; called by mutect2, varscan2
- BAAT | c.16G>A p.A6T | Missense Mutation (SNP) | VAF 22/58 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.931); catalogued as COSV52291873; called by muse, mutect2, varscan2
- BACH1 | c.1507G>A p.D503N | Missense Mutation (SNP) | VAF 20/55 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.757); catalogued as COSV54518055; called by muse, mutect2, varscan2
- BACH1 | c.2147G>A p.R716H | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT tolerated (0.46); PolyPhen possibly damaging (0.469); catalogued as rs773339742, COSV54520052; called by muse, mutect2, varscan2
- BACH2 | c.2321C>T p.A774V | Missense Mutation (SNP) | VAF 14/46 reads (30%) | SIFT tolerated (0.29); PolyPhen benign (0.028); catalogued as rs375103380, COSV57612203; called by muse, mutect2, varscan2
- BAG3 | c.470C>T p.A157V | Missense Mutation (SNP) | VAF 32/88 reads (36%) | SIFT tolerated (0.09); PolyPhen benign (0.015); catalogued as rs541080567, COSV64841963, COSV64842346; called by muse, mutect2, varscan2
- BAG6 | c.3473G>T p.S1158I (on ENST00000676571; = p.S1111I on NM_080702.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 20/48 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.115); catalogued as COSV52991012; called by muse, mutect2, varscan2
- BAHCC1 | c.3677C>T p.S1226L | Missense Mutation (SNP) | VAF 4/19 reads (21%) | SIFT tolerated (0.48); PolyPhen benign (0.001); catalogued as rs868923062; called by muse, mutect2, varscan2
- BAHCC1 | c.6952G>A p.D2318N | Missense Mutation (SNP) | VAF 10/56 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs782736031, COSV100311763; called by muse, mutect2, varscan2
- BAHD1 | c.2104G>A p.A702T | Missense Mutation (SNP) | VAF 34/110 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV69084553; called by muse, mutect2, varscan2
- BAIAP2L1 | c.1397C>T p.A466V | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT tolerated (0.55); PolyPhen benign (0); catalogued as rs747137198; called by muse, mutect2, varscan2
- BAIAP2L2 | c.544C>T p.R182W | Missense Mutation (SNP) | VAF 14/35 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100207250; called by muse, mutect2, varscan2
- BAIAP3 | c.1070C>A p.P357H | Missense Mutation (SNP) | VAF 34/100 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100181517; called by muse, mutect2, varscan2
- BANK1 | c.707G>A p.R236H | Missense Mutation (SNP) | VAF 21/57 reads (37%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as rs777895274, COSV59842328; called by muse, mutect2, varscan2
- BARD1 | c.104C>T p.A35V | Missense Mutation (SNP) | VAF 19/46 reads (41%) | SIFT tolerated (0.06); PolyPhen benign (0.142); catalogued as rs786203646; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BARHL1 | c.61G>A p.A21T | Missense Mutation (SNP) | VAF 46/90 reads (51%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.019); catalogued as rs1388115023, COSV55037727; called by muse, mutect2, varscan2
- BATF | c.196G>A p.A66T | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT tolerated (0.81); PolyPhen probably damaging (0.994); catalogued as COSV54376344; called by muse, mutect2, varscan2
- BAZ1A | c.3853C>T p.R1285C | Missense Mutation (SNP) | VAF 21/49 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.642); catalogued as rs560209924, COSV62411199, COSV62411670; called by muse, mutect2, varscan2
- BAZ1B | c.1364G>A p.R455Q | Missense Mutation (SNP) | VAF 10/54 reads (19%) | SIFT tolerated (0.19); PolyPhen benign (0.084); catalogued as rs782409459; called by muse, mutect2, varscan2
- BAZ1B | c.692A>C p.K231T | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.922); catalogued as rs1554575742; called by muse, mutect2, varscan2
- BAZ2B | c.4103C>T p.A1368V | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.146); catalogued as rs764609647, COSV58609868; called by mutect2, varscan2
- BAZ2B | c.1292G>A p.R431Q | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT tolerated, low confidence (0.36); PolyPhen probably damaging (0.968); catalogued as rs762616502; called by mutect2, varscan2
- BBOF1 | c.1352G>A p.R451Q | Missense Mutation (SNP) | VAF 19/47 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1469003732, COSV63246864; called by muse, mutect2, varscan2
- BBS9 | c.1799G>A p.R600H (on ENST00000242067 / NM_001348036.1; = p.R560H on NM_014451.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 37/55 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs749018243, COSV54189065; called by muse, mutect2, varscan2
- BCAM | c.293G>A p.R98H | Missense Mutation (SNP) | VAF 11/42 reads (26%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.972); catalogued as rs776003390, COSV104373265; called by muse, mutect2, varscan2
- BCAR1 | c.2392A>G p.T798A | Missense Mutation (SNP) | VAF 12/88 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.959); catalogued as rs1276288174; called by muse, mutect2, varscan2
- BCAR1 | c.16G>A p.V6M | Missense Mutation (SNP) | VAF 13/37 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.773); catalogued as rs1362883963, COSV50784879; called by muse, mutect2, varscan2
- BCAS3 | c.68G>A p.R23H | Missense Mutation (SNP) | VAF 16/39 reads (41%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.964); catalogued as rs755073133, COSV66778193; called by muse, mutect2, varscan2
- BCHE | c.252G>T p.W84C | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.779); catalogued as rs1560023728; called by muse, mutect2
- BCKDK | c.70G>A p.A24T | Missense Mutation (SNP) | VAF 13/25 reads (52%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0.005); catalogued as rs372044087; called by muse, mutect2, varscan2
- BCL2 | c.101A>G p.D34G | Missense Mutation (SNP) | VAF 13/67 reads (19%) | SIFT tolerated (0.09); PolyPhen benign (0.001); catalogued as COSV61383685, COSV61399705; called by muse, mutect2, varscan2
- BCL2L13 | c.1049C>T p.T350I | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.296); catalogued as rs1421906874; called by muse, mutect2, varscan2
- BCL2L2 | c.100G>A p.G34R | Missense Mutation (SNP) | VAF 14/39 reads (36%) | SIFT tolerated (0.06); PolyPhen benign (0.277); catalogued as rs773144952, COSV51636146; called by muse, mutect2, varscan2
- BCL6B | c.877C>T p.R293C | Missense Mutation (SNP) | VAF 8/53 reads (15%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as rs770283128, COSV53427614; called by mutect2, varscan2
- BCL9 | c.1682G>A p.R561H | Missense Mutation (SNP) | VAF 23/65 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs369189038; called by muse, mutect2, varscan2
- BCL9 | c.3848G>T p.R1283I | Missense Mutation (SNP) | VAF 17/33 reads (52%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); catalogued as COSV52345168; called by muse, mutect2, varscan2
- BCLAF1 | c.65G>A p.R22Q | Missense Mutation (SNP) | VAF 24/74 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.986); catalogued as rs778450329; called by muse, mutect2, varscan2
- BCLAF3 | c.1685G>A p.R562Q | Missense Mutation (SNP) | VAF 18/107 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1460755239; called by muse, mutect2, varscan2
- BCOR | c.479T>C p.V160A | Missense Mutation (SNP) | VAF 14/96 reads (15%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.986); catalogued as rs1459702445; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BCORL1 | c.4408G>A p.D1470N | Missense Mutation (SNP) | VAF 14/77 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.222); catalogued as rs200861335; called by muse, mutect2, varscan2
- BCS1L | c.350G>A p.R117Q | Missense Mutation (SNP) | VAF 24/52 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55306711; called by muse, mutect2, varscan2
- BDKRB2 | c.931G>A p.D311N | Missense Mutation (SNP) | VAF 18/62 reads (29%) | SIFT tolerated (0.06); PolyPhen benign (0.28); catalogued as rs763874568, COSV100021430; called by muse, mutect2, varscan2
- BEGAIN | c.605C>T p.A202V | Missense Mutation (SNP) | VAF 23/57 reads (40%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.461); catalogued as rs530174214; called by muse, mutect2, varscan2
- BEND2 | c.691G>A p.G231S | Missense Mutation (SNP) | VAF 8/62 reads (13%) | SIFT tolerated (0.53); PolyPhen benign (0.001); catalogued as rs770338351, COSV66216734; called by mutect2, varscan2
- BEND4 | c.1493G>A p.R498Q | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.992); catalogued as rs373680999; called by muse, mutect2, varscan2
- BGN | c.970G>A p.G324S | Missense Mutation (SNP) | VAF 20/58 reads (34%) | SIFT tolerated (0.16); PolyPhen benign (0.21); catalogued as COSV59035785; called by muse, varscan2
- BGN | c.985C>T p.R329W | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs1569532459; called by muse, varscan2
- BICDL1 | c.1219G>A p.A407T | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT tolerated (0.08); PolyPhen benign (0.05); catalogued as rs1355968585, COSV57494374; called by muse, mutect2, varscan2
- BICDL2 | c.1453G>A p.A485T | Missense Mutation (SNP) | VAF 4/11 reads (36%) | SIFT tolerated (0.31); PolyPhen benign (0.003); catalogued as rs1318800113; called by muse, mutect2
- BICRAL | c.1775C>T p.S592F | Missense Mutation (SNP) | VAF 26/77 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.037); catalogued as rs754908273; called by muse, mutect2, varscan2
- BIN1 | c.1252G>A p.D418N | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV52119848; called by muse, mutect2, varscan2
- BIRC6 | c.38T>C p.V13A | Missense Mutation (SNP) | VAF 8/90 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.081); catalogued as rs1246101886; called by muse, mutect2
- BIVM-ERCC5 | c.1496G>A p.R499H | Missense Mutation (SNP) | VAF 22/81 reads (27%) | SIFT tolerated (0.06); PolyPhen benign (0.029); catalogued as rs140917545; called by muse, mutect2
- BIVM-ERCC5 | c.3017A>G p.Y1006C | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.081); catalogued as rs914400125; called by muse, mutect2
- BIVM-ERCC5 | c.4700T>C p.V1567A | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT tolerated, low confidence (0.94); PolyPhen benign (0); catalogued as COSV63247786; called by muse, mutect2, varscan2
- BLK | c.811C>A p.L271M | Missense Mutation (SNP) | VAF 9/104 reads (9%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.709); catalogued as rs1372364673; called by muse, mutect2
- BLK | c.1076G>A p.R359H | Missense Mutation (SNP) | VAF 19/44 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.923); catalogued as rs771699695; called by muse, mutect2, varscan2
- BMP2 | c.329G>A p.R110H | Missense Mutation (SNP) | VAF 36/88 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV101122107; called by muse, varscan2
- BMP5 | c.290C>T p.S97L | Missense Mutation (SNP) | VAF 40/108 reads (37%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as rs768565166, COSV63703116; called by muse, varscan2
- BMPER | c.943T>C p.S315P | Missense Mutation (SNP) | VAF 14/92 reads (15%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.959); catalogued as rs1230281562; called by muse, mutect2, varscan2
- BMS1 | c.3295C>T p.R1099* | Nonsense Mutation (SNP) | VAF 19/130 reads (15%) | catalogued as rs1213981443, COSV100996834; called by muse, mutect2, varscan2
- BMS1 | c.3647C>T p.T1216M | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs773249299; called by muse, varscan2
- BMT2 | c.1078C>T p.R360* | Nonsense Mutation (SNP) | VAF 15/50 reads (30%) | catalogued as COSV51775023; called by muse, mutect2, varscan2
- BNC2 | c.2708C>T p.S903L | Missense Mutation (SNP) | VAF 18/60 reads (30%) | SIFT tolerated (0.65); PolyPhen benign (0.027); catalogued as rs752551063; called by muse, mutect2, varscan2
- BNC2 | c.1462C>T p.R488C | Missense Mutation (SNP) | VAF 35/114 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV66144492; called by muse, mutect2, varscan2
- BNIP1 | c.319G>A p.D107N | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.629); catalogued as rs370583969; called by muse, mutect2, varscan2
- BOD1L1 | c.8332C>T p.L2778F | Missense Mutation (SNP) | VAF 7/37 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.133); catalogued as COSV99240600; called by muse, mutect2, varscan2
- BOD1L1 | c.1477C>T p.R493* | Nonsense Mutation (SNP) | VAF 15/60 reads (25%) | catalogued as rs770882506, COSV50008871; called by muse, mutect2, varscan2
- BPGM | c.634C>A p.L212I | Missense Mutation (SNP) | VAF 23/63 reads (37%) | SIFT tolerated (1); PolyPhen possibly damaging (0.492); catalogued as rs200244541, COSV61326413; called by muse, mutect2, varscan2
- BPHL | c.793C>T p.H265Y | Missense Mutation (SNP) | VAF 11/66 reads (17%) | SIFT tolerated (0.28); PolyPhen benign (0.031); catalogued as COSV61318720; called by muse, mutect2, varscan2
- BPIFC | c.1149C>T p.F383= | Splice Region (SNP) | VAF 20/116 reads (17%) | catalogued as rs200868839, COSV55910552; called by muse, mutect2
- BRCA1 | c.4681A>G p.T1561A | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT tolerated (0.17); PolyPhen benign (0.017); catalogued as CD113838; called by muse, mutect2, varscan2
- BRCA1 | c.4079G>T p.S1360I | Missense Mutation (SNP) | VAF 24/71 reads (34%) | SIFT tolerated (0.08); PolyPhen benign (0.001); catalogued as COSV58803495; called by muse, mutect2, varscan2
- BRCA2 | c.2451G>T p.K817N | Missense Mutation (SNP) | VAF 4/23 reads (17%) | SIFT tolerated (0.13); PolyPhen benign (0.017); catalogued as rs767686668, COSV66451277; ClinVar: uncertain significance; called by mutect2, varscan2
- BRCA2 | c.4063G>A p.D1355N | Missense Mutation (SNP) | VAF 16/42 reads (38%) | SIFT tolerated (0.41); PolyPhen benign (0.059); catalogued as COSV66460347; called by muse, varscan2
- BRCA2 | c.5062G>T p.E1688* | Nonsense Mutation (SNP) | VAF 10/26 reads (38%) | catalogued as COSV101204522; called by muse, mutect2, varscan2
- BRCA2 | c.6986C>T p.P2329L | Missense Mutation (SNP) | VAF 8/58 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs80358925, CM1210131; ClinVar: conflicting interpretations of pathogenicity / likely benign / uncertain significance; called by mutect2, varscan2
- BRD2 | c.965G>A p.R322H | Missense Mutation (SNP) | VAF 14/51 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100875538; called by muse, varscan2
- BRD4 | c.3289C>T p.R1097C | Missense Mutation (SNP) | VAF 24/64 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.973); catalogued as rs1234699192, COSV54585613; called by muse, mutect2, varscan2
- BRINP1 | c.316C>T p.R106C | Missense Mutation (SNP) | VAF 28/98 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs768650077, COSV56292458; called by muse, varscan2
- BRINP3 | c.2041C>T p.R681W | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.867); catalogued as rs199983605, COSV66532306, COSV66534597; called by muse, mutect2, varscan2
- BRIP1 | c.689C>T p.S230L | Missense Mutation (SNP) | VAF 9/58 reads (16%) | SIFT tolerated (0.09); PolyPhen benign (0.015); catalogued as rs759031349; ClinVar: uncertain significance / likely benign; called by mutect2, varscan2
- BRPF1 | c.1983+7G>A | Splice Region (SNP) | VAF 10/64 reads (16%) | catalogued as rs751452778; called by mutect2, varscan2
- BRS3 | c.988C>A p.L330I | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65711034; called by muse, mutect2, varscan2
- BRSK1 | c.1009C>T p.R337C | Missense Mutation (SNP) | VAF 6/72 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.835); catalogued as COSV58665953; called by muse, mutect2
- BRSK1 | c.2282G>A p.R761Q | Missense Mutation (SNP) | VAF 5/12 reads (42%) | SIFT tolerated, low confidence (0.27); PolyPhen possibly damaging (0.885); catalogued as rs771530018, COSV58593080; called by muse, mutect2, varscan2
- BRSK2 | c.275A>G p.Y92C | Missense Mutation (SNP) | VAF 26/67 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs1170728470; called by muse, mutect2, varscan2
- BRWD3 | c.2350C>T p.R784C | Missense Mutation (SNP) | VAF 40/79 reads (51%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.608); catalogued as rs142223428; called by muse, mutect2, varscan2
- BSN | c.10436C>T p.A3479V | Missense Mutation (SNP) | VAF 19/65 reads (29%) | SIFT tolerated (0.11); PolyPhen benign (0.005); catalogued as rs201323732; called by muse, mutect2, varscan2
- BTBD11 | c.3206A>G p.D1069G (on ENST00000280758 / NM_001018072.2; = p.D606G on NM_001017523.2) | Missense Mutation (SNP) | VAF 11/68 reads (16%) | SIFT tolerated (0.76); PolyPhen probably damaging (0.989); catalogued as rs755362451; called by muse, mutect2, varscan2
- BTBD3 | c.1166G>A p.R389H | Missense Mutation (SNP) | VAF 13/30 reads (43%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.663); catalogued as rs1331431428; called by muse, mutect2, varscan2
- BTBD6 | c.1318G>A p.E440K | Missense Mutation (SNP) | VAF 10/90 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); catalogued as rs1393102254; called by muse, mutect2, varscan2
- BTBD7 | c.1933G>A p.E645K | Missense Mutation (SNP) | VAF 18/54 reads (33%) | SIFT tolerated (0.09); PolyPhen benign (0.097); catalogued as rs374622208; called by muse, mutect2, varscan2
- BTBD8 | c.625G>A p.D209N | Missense Mutation (SNP) | VAF 14/59 reads (24%) | SIFT tolerated (0.61); PolyPhen benign (0.1); catalogued as rs754915147, COSV100730473; called by muse, mutect2, varscan2
- BTG2 | c.335G>A p.R112H | Missense Mutation (SNP) | VAF 6/56 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs752692832; called by mutect2, varscan2
- BTK | c.82C>T p.R28C | Missense Mutation (SNP) | VAF 24/80 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM040689, CM980262, COSV58117488; called by muse, mutect2, varscan2
- BTN3A1 | c.874G>T p.E292* | Nonsense Mutation (SNP) | VAF 9/35 reads (26%) | catalogued as COSV50025121; called by muse, mutect2, varscan2
- BTN3A2 | c.574G>A p.A192T | Missense Mutation (SNP) | VAF 13/79 reads (16%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.575); catalogued as rs1220657079; called by muse, mutect2, varscan2
- BTRC | c.1528C>T p.R510C (on ENST00000370187 / NM_033637.4; = p.R474C on NM_003939.5) | Missense Mutation (SNP) | VAF 15/61 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV64579491; called by muse, mutect2, varscan2
- BUD23 | c.124C>T p.R42* | Nonsense Mutation (SNP) | VAF 23/150 reads (15%) | catalogued as rs782720715; called by muse, mutect2, varscan2
- BUD23 | c.626C>T p.S209L | Missense Mutation (SNP) | VAF 49/132 reads (37%) | SIFT tolerated (0.08); PolyPhen benign (0.16); catalogued as rs1266528723, COSV56094350; called by muse, mutect2, varscan2
- BYSL | c.664C>T p.P222S | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs368831348; called by mutect2, varscan2
- BYSL | c.1213C>T p.L405F | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.992); catalogued as COSV100026790; called by muse, mutect2, varscan2
- C10orf62 | c.429C>A p.H143Q | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.043); catalogued as rs758692283; called by muse, mutect2
- C10orf71 | c.1732G>A p.A578T | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT tolerated (0.5); PolyPhen benign (0.003); catalogued as rs771359282; called by muse, varscan2
- C11orf16 | c.817T>G p.C273G | Missense Mutation (SNP) | VAF 15/46 reads (33%) | SIFT tolerated (0.09); PolyPhen benign (0.015); catalogued as COSV58168409; called by muse, mutect2, varscan2
- C11orf24 | c.1184C>T p.A395V | Missense Mutation (SNP) | VAF 14/57 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.155); catalogued as COSV100422440; called by muse, mutect2, varscan2
- C11orf42 | c.565C>T p.R189W | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.437); catalogued as rs138832219; called by muse, mutect2, varscan2
- C11orf42 | c.779C>T p.T260M | Missense Mutation (SNP) | VAF 18/51 reads (35%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.464); catalogued as rs373015994; called by muse, varscan2
- C12orf4 | c.1004G>A p.R335Q | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.954); catalogued as rs532268400, COSV54205508; called by muse, mutect2, varscan2
- C12orf4 | c.917G>A p.R306Q | Missense Mutation (SNP) | VAF 15/51 reads (29%) | SIFT tolerated (0.6); PolyPhen benign (0.024); catalogued as rs779424816; called by muse, mutect2, varscan2
- C12orf56 | c.1031C>A p.S344Y (on ENST00000543942 / NM_001170633.2; = p.S184Y on NM_001099676.3) | Missense Mutation (SNP) | VAF 17/51 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.136); catalogued as rs1169647482, COSV100399173; called by muse, mutect2, varscan2
- C14orf39 | c.596C>T p.A199V | Missense Mutation (SNP) | VAF 23/57 reads (40%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.996); catalogued as COSV58779608; called by muse, mutect2, varscan2
- C16orf54 | c.296C>T p.A99V | Missense Mutation (SNP) | VAF 14/24 reads (58%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.009); catalogued as rs535090241, COSV61476926; called by muse, varscan2
- C17orf64 | c.652C>A p.P218T | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT tolerated, low confidence (0.35); PolyPhen benign (0.003); catalogued as rs202131111; called by muse, mutect2, varscan2
- C18orf54 | c.466C>T p.R156C | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as rs755895888, COSV100266619, COSV55619083; called by mutect2, varscan2
- C19orf57 | c.1471G>A p.D491N | Missense Mutation (SNP) | VAF 22/80 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.026); catalogued as rs1371889944, COSV60967786; called by muse, varscan2
- C1GALT1 | c.689A>G p.D230G | Missense Mutation (SNP) | VAF 13/38 reads (34%) | SIFT tolerated (0.73); PolyPhen benign (0); catalogued as rs1454912932; called by muse, mutect2, varscan2
- C1QB | c.416G>A p.R139H | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.946); catalogued as rs372067838; called by muse, mutect2, varscan2
- C1QTNF1 | c.224G>A p.R75H | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT tolerated (0.13); PolyPhen benign (0.197); catalogued as rs776839033, COSV59260951; called by mutect2, varscan2
- C1QTNF1 | c.631A>C p.I211L | Missense Mutation (SNP) | VAF 39/116 reads (34%) | SIFT tolerated (0.44); PolyPhen benign (0.005); catalogued as COSV59263348; called by muse, mutect2, varscan2
- C1R | c.1619T>C p.V540A (on ENST00000536053 / NM_001354346.2; = p.V526A on NM_001733.7) | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.709); catalogued as rs772357482; called by muse, mutect2, varscan2
- C1orf141 | c.933G>T p.W311C | Missense Mutation (SNP) | VAF 29/66 reads (44%) | SIFT tolerated (0.12); PolyPhen benign (0.074); catalogued as COSV63992223, COSV63992615; called by muse, mutect2, varscan2
- C20orf144 | c.62C>T p.P21L | Missense Mutation (SNP) | VAF 13/34 reads (38%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs1275945984; called by muse, mutect2, varscan2
- C2CD2L | c.1567C>T p.R523W | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as rs758521254; called by muse, mutect2, varscan2
- C2CD5 | c.548G>A p.R183H | Missense Mutation (SNP) | VAF 32/89 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as COSV61724254; called by muse, mutect2, varscan2
- C2CD6 | c.76G>A p.A26T | Missense Mutation (SNP) | VAF 16/130 reads (12%) | SIFT tolerated (0.92); PolyPhen benign (0); catalogued as rs777433403, COSV53795069; called by mutect2, varscan2
- C3 | c.3760C>T p.R1254C | Missense Mutation (SNP) | VAF 21/63 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1255849792; called by muse, varscan2
- C3orf14 | c.256C>T p.R86C | Missense Mutation (SNP) | VAF 17/46 reads (37%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.629); catalogued as rs1269288060, COSV51707722; called by muse, mutect2, varscan2
- C3orf22 | c.323G>A p.R108H | Missense Mutation (SNP) | VAF 27/80 reads (34%) | SIFT tolerated (0.55); PolyPhen benign (0.001); catalogued as rs202039278, COSV100559560; called by muse, mutect2, varscan2
- C3orf70 | c.581C>T p.A194V | Missense Mutation (SNP) | VAF 15/47 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as rs756242736; called by muse, mutect2, varscan2
- C4B | c.3898C>T p.R1300C | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT tolerated (0.14); PolyPhen benign (0.315); catalogued as rs751412917; called by muse, mutect2, varscan2
- C4BPA | c.15A>C p.K5N | Missense Mutation (SNP) | VAF 4/23 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.014); catalogued as COSV65536285; called by muse, mutect2
- C5 | c.3731C>T p.T1244M | Missense Mutation (SNP) | VAF 15/43 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); catalogued as rs754562499, COSV56323862; called by muse, mutect2, varscan2
- C5 | c.2393A>G p.E798G | Missense Mutation (SNP) | VAF 7/58 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56332175; called by muse, varscan2
- C5AR2 | c.508G>A p.A170T | Missense Mutation (SNP) | VAF 17/78 reads (22%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.738); catalogued as rs1479076732, COSV99953730; called by muse, mutect2, varscan2
- C6orf58 | c.328A>G p.T110A | Missense Mutation (SNP) | VAF 6/98 reads (6%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.925); catalogued as COSV61666587; called by muse, mutect2
- C7 | c.472A>G p.T158A | Missense Mutation (SNP) | VAF 27/68 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV57475648; called by muse, mutect2, varscan2
- C7orf31 | c.862C>A p.L288M | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT tolerated (0.09); PolyPhen benign (0.301); catalogued as COSV52221099; called by muse, mutect2, varscan2
- C8orf58 | c.569G>A p.R190H | Missense Mutation (SNP) | VAF 14/40 reads (35%) | SIFT deleterious (0.05); PolyPhen benign (0.017); catalogued as rs373734103, COSV99254423; called by muse, mutect2, varscan2
- C8orf74 | c.289G>A p.D97N | Missense Mutation (SNP) | VAF 11/45 reads (24%) | SIFT tolerated (0.17); PolyPhen benign (0.12); catalogued as COSV100262182; called by muse, mutect2, varscan2
- C9orf135 | c.625T>C p.Y209H | Missense Mutation (SNP) | VAF 35/96 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.181); catalogued as rs1460264853; called by muse, mutect2, varscan2
- CA10 | c.175C>A p.L59I | Missense Mutation (SNP) | VAF 20/66 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs1369735357; called by muse, varscan2
- CA7 | c.232C>T p.R78* | Nonsense Mutation (SNP) | VAF 11/36 reads (31%) | catalogued as rs1335028612, COSV58156086; called by muse, varscan2
- CA9 | c.898G>A p.A300T | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT tolerated (0.69); PolyPhen benign (0.003); catalogued as rs746857543, COSV100253504, COSV61406222; called by muse, mutect2, varscan2
- CABP4 | c.160C>T p.R54C | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.265); catalogued as rs762763330; called by muse, varscan2
- CABP4 | c.640G>A p.A214T | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1216159600; called by muse, mutect2, varscan2
- CABS1 | c.357A>C p.K119N | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT tolerated (0.09); PolyPhen benign (0.383); catalogued as COSV56733448; called by muse, mutect2, varscan2
- CACHD1 | c.1337G>A p.R446Q | Missense Mutation (SNP) | VAF 14/86 reads (16%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.921); catalogued as rs369788799; called by muse, mutect2, varscan2
- CACNA1A | c.203G>A p.R68Q | Missense Mutation (SNP) | VAF 18/88 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.386); catalogued as rs576099495, COSV64197963; called by muse, varscan2
- CACNA1A | c.158C>T p.A53V | Missense Mutation (SNP) | VAF 13/78 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.776); catalogued as COSV64201789; called by muse, varscan2
- CACNA1B | c.476G>A p.G159D | Missense Mutation (SNP) | VAF 39/99 reads (39%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as rs1236721981; called by muse, mutect2, varscan2
- CACNA1B | c.5329C>T p.R1777C | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.677); catalogued as COSV53120518; called by muse, mutect2, varscan2
- CACNA1F | c.4189C>T p.R1397W | Missense Mutation (SNP) | VAF 15/32 reads (47%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as rs782428223, COSV99058891; called by muse, mutect2, varscan2
- CACNA1F | c.2071C>T p.R691* | Nonsense Mutation (SNP) | VAF 10/108 reads (9%) | catalogued as rs782074040, CM055909, COSV100545278; called by muse, mutect2
- CACNA1F | c.1145C>T p.A382V | Missense Mutation (SNP) | VAF 25/60 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs781984852, COSV100545393, COSV59907098; called by muse, mutect2, varscan2
- CACNA1F | c.739G>A p.V247I | Missense Mutation (SNP) | VAF 22/54 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.542); catalogued as COSV59903290; called by muse, mutect2, varscan2
- CACNA1G | c.4675C>T p.R1559C | Missense Mutation (SNP) | VAF 11/106 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs756359036; called by mutect2, varscan2
- CACNA1G | c.6503C>T p.S2168F | Missense Mutation (SNP) | VAF 24/138 reads (17%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0); catalogued as rs760712312; called by muse, mutect2, varscan2
- CACNA1H | c.5827C>T p.P1943S | Missense Mutation (SNP) | VAF 23/91 reads (25%) | SIFT tolerated (0.11); PolyPhen benign (0.1); catalogued as rs1471740431; called by muse, mutect2, varscan2
- CACNA1S | c.3157G>A p.A1053T | Missense Mutation (SNP) | VAF 32/81 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1558062351; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CACNA1S | c.1498G>A p.D500N | Missense Mutation (SNP) | VAF 24/68 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs1287772954, COSV100754794; called by muse, mutect2, varscan2
- CACNA2D1 | c.962C>T p.A321V | Missense Mutation (SNP) | VAF 10/63 reads (16%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.955); catalogued as rs1416010629, COSV62375073; called by muse, mutect2, varscan2
- CACNA2D3 | c.349C>T p.H117Y | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.745); catalogued as rs1403539500; called by muse, varscan2
- CACNA2D3 | c.823G>A p.A275T | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1471047657; called by muse, mutect2, varscan2
- CACNA2D4 | c.1847C>T p.S616L | Missense Mutation (SNP) | VAF 32/127 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.124); catalogued as rs200636614, COSV54949212; called by muse, mutect2, varscan2
- CACNB3 | c.658G>A p.D220N | Missense Mutation (SNP) | VAF 34/81 reads (42%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); catalogued as rs924688203, COSV56398604; called by muse, mutect2, varscan2
- CACNB4 | c.1517G>A p.R506Q | Missense Mutation (SNP) | VAF 17/98 reads (17%) | SIFT deleterious, low confidence (0.05); PolyPhen probably damaging (0.945); catalogued as rs775115799; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CAD | c.2485C>T p.L829F | Missense Mutation (SNP) | VAF 28/71 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1311495800; called by muse, mutect2, varscan2
- CADPS2 | c.2809C>T p.R937C | Missense Mutation (SNP) | VAF 18/67 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs200436780; called by muse, mutect2, varscan2
- CALB1 | c.766C>A p.L256I | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.96); catalogued as COSV99618244; called by muse, mutect2, varscan2
- CALCOCO1 | c.1438C>T p.R480C | Missense Mutation (SNP) | VAF 27/64 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as rs1030520322, COSV100017258; called by muse, mutect2, varscan2
- CALCOCO1 | c.908C>T p.A303V | Missense Mutation (SNP) | VAF 12/48 reads (25%) | SIFT tolerated (0.71); PolyPhen benign (0.013); catalogued as rs776248946; called by muse, mutect2, varscan2
- CALHM1 | c.541C>T p.R181C | Missense Mutation (SNP) | VAF 13/21 reads (62%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.781); catalogued as rs769331766; called by muse, varscan2
- CALHM2 | c.892C>T p.R298C | Missense Mutation (SNP) | VAF 10/80 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.94); catalogued as rs1420917138; called by muse, mutect2, varscan2
- CALU | c.10C>T p.R4* | Nonsense Mutation (SNP) | VAF 16/32 reads (50%) | catalogued as rs143724366; called by muse, mutect2, varscan2
- CALU | c.662A>G p.D221G | Missense Mutation (SNP) | VAF 38/115 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as rs1030837162; called by muse, mutect2, varscan2
- CAMK2B | c.1673C>T p.A558V | Missense Mutation (SNP) | VAF 24/57 reads (42%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.967); catalogued as rs749755008, COSV51667434; called by muse, mutect2, varscan2
- CAMK2G | c.875G>A p.R292H | Missense Mutation (SNP) | VAF 7/46 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.71); catalogued as CM1211472; called by mutect2, varscan2
- CAMKK1 | c.1370G>A p.R457H | Missense Mutation (SNP) | VAF 13/42 reads (31%) | SIFT tolerated (0.45); PolyPhen benign (0.012); catalogued as rs776101005, COSV50117754; called by muse, mutect2, varscan2
- CAMKMT | c.370A>C p.N124H | Missense Mutation (SNP) | VAF 26/56 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101035399; called by muse, varscan2
- CAMKV | c.358C>T p.R120* | Nonsense Mutation (SNP) | VAF 20/57 reads (35%) | catalogued as COSV56556084; called by muse, mutect2, varscan2
- CAMLG | c.484G>A p.A162T | Missense Mutation (SNP) | VAF 16/35 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as rs558413025; called by muse, mutect2, varscan2
- CAMSAP3 | c.154G>A p.V52M | Missense Mutation (SNP) | VAF 44/106 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV50332429; called by muse, mutect2, varscan2
- CAMSAP3 | c.1321G>A p.A441T | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as COSV50331425; called by mutect2, varscan2
- CAMSAP3 | c.2768G>T p.W923L | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT tolerated (0.32); PolyPhen benign (0.001); catalogued as COSV50332161; called by mutect2, varscan2
- CAMTA1 | c.4814G>A p.R1605Q | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs1412115173; called by muse, mutect2
- CAMTA1 | c.4942C>T p.R1648C | Missense Mutation (SNP) | VAF 13/40 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs372954423; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CAMTA2 | c.3227C>T p.A1076V | Missense Mutation (SNP) | VAF 18/118 reads (15%) | SIFT tolerated (0.14); PolyPhen benign (0.072); catalogued as COSV99236795; called by muse, varscan2
- CAND1 | c.3221C>T p.T1074M | Missense Mutation (SNP) | VAF 35/91 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1484084757; called by muse, mutect2, varscan2
- CAND2 | c.139C>T p.R47C | Missense Mutation (SNP) | VAF 13/48 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.836); catalogued as rs370436475; called by muse, mutect2, varscan2
- CAND2 | c.1865G>A p.R622Q (on ENST00000456430 / NM_001162499.2; = p.R529Q on NM_012298.3) | Missense Mutation (SNP) | VAF 16/48 reads (33%) | SIFT tolerated (0.11); PolyPhen benign (0.154); catalogued as rs780125791; called by muse, mutect2, varscan2
- CAND2 | c.2716G>A p.A906T (on ENST00000456430 / NM_001162499.2; = p.A813T on NM_012298.3) | Missense Mutation (SNP) | VAF 10/71 reads (14%) | SIFT tolerated (0.42); PolyPhen benign (0.003); catalogued as COSV55994619; called by muse, varscan2
- CAPN1 | c.1406C>T p.A469V | Missense Mutation (SNP) | VAF 13/102 reads (13%) | SIFT tolerated (0.09); PolyPhen benign (0.212); catalogued as rs1217528784, COSV54201281; called by muse, mutect2, varscan2
- CAPN10 | c.778C>T p.R260W | Missense Mutation (SNP) | VAF 34/104 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs745718891; called by muse, varscan2
- CAPN12 | c.68G>A p.R23H | Missense Mutation (SNP) | VAF 19/69 reads (28%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as rs763733422; called by muse, mutect2, varscan2
- CAPN13 | c.1249C>T p.R417W | Missense Mutation (SNP) | VAF 18/54 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as rs201062209, COSV99699998; called by muse, mutect2, varscan2
- CAPN13 | c.73C>T p.R25W | Missense Mutation (SNP) | VAF 28/54 reads (52%) | SIFT tolerated (0.06); PolyPhen benign (0.045); catalogued as rs746445685, COSV54431598; called by muse, varscan2
- CAPN3 | c.5C>T p.P2L | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs373919252, COSV58820318; called by muse, mutect2, varscan2
- CAPN6 | c.1487A>G p.E496G | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV60693943; called by muse, mutect2, varscan2
- CAPN6 | c.860G>A p.G287E | Missense Mutation (SNP) | VAF 19/63 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60694403; called by muse, mutect2, varscan2
15,324 further variants in this file (11,210 protein-altering or splice-affecting, 3,745 silent, 369 other) are not listed here.
